Somatic mutation profile of tumor specimen TCGA-A6-5665-01B (aliquot TCGA-A6-5665-01B-03D-2298-08) from TCGA case TCGA-A6-5665, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 84.6 years (30,915 days).
Specimen TCGA-A6-5665-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c83694b4-bd03-430c-8304-9847ea9e68da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-5665-10A (Blood Derived Normal), aliquot TCGA-A6-5665-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18eb3e5b-a608-4cdf-a8e7-afc181c456e6

The open-access MAF lists 2,162 somatic variants for this specimen: 1,677 protein-altering or splice-affecting, 437 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,089, Silent 437, Frame Shift Del 293, Frame Shift Ins 164, Nonsense Mutation 62, Splice Site 31, Intron 19, Splice Region 17, In Frame Del 13, 3'UTR 10, RNA 7, 5'UTR 5.

Variants (750 of 2,162; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO5 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 84/220 reads (38%) | catalogued as rs1168346560, CM117893, COSV61083716; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APOA1 | c.85del p.Q29Rfs*7 | Frame Shift Del (DEL) | VAF 53/223 reads (24%) | catalogued as rs753348565, CD961783; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ATM | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 67/204 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs202160435, COSV53723910, COSV53729033; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1155dup p.I386Hfs*56 | Frame Shift Ins (INS) | VAF 108/334 reads (32%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, varscan2
- AXIN2 | c.1994dup p.N666Qfs*41 | Frame Shift Ins (INS) | VAF 30/88 reads (34%) | catalogued as rs267606674; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AXL | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 73/186 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs374699228; called by muse, mutect2, varscan2
- B4GALNT1 | c.263dup p.L89Pfs*13 | Frame Shift Ins (INS) | VAF 77/240 reads (32%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BCL10 | c.499del p.S167Lfs*6 | Frame Shift Del (DEL) | VAF 114/369 reads (31%) | catalogued as rs387906350, COSV65354275; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 104/367 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRCA2 | c.7543dup p.T2515Nfs*24 | Frame Shift Ins (INS) | VAF 186/701 reads (27%) | catalogued as rs80359657; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CACNA1A | c.3544dup p.L1182Pfs*38 | Frame Shift Ins (INS) | VAF 12/54 reads (22%) | catalogued as rs757953057; ClinVar: pathogenic; called by mutect2, varscan2
- CDK12 | c.2669G>A p.R890H | Missense Mutation (SNP) | VAF 59/202 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71000029; called by muse, mutect2, varscan2
- CENPF | c.5920dup p.T1974Nfs*9 | Frame Shift Ins (INS) | VAF 41/148 reads (28%) | catalogued as rs757531591; ClinVar: pathogenic; called by mutect2, varscan2
- CHD8 | c.5607del p.D1870Tfs*21 (on ENST00000646647 / NM_001170629.2; = p.D1591Tfs*21 on NM_020920.4) | Frame Shift Del (DEL) | VAF 30/135 reads (22%) | catalogued as rs774152851; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- COL1A1 | c.2424del p.G809Afs*299 | Frame Shift Del (DEL) | VAF 34/126 reads (27%) | catalogued as rs1114167391, CD123308; ClinVar: pathogenic; called by mutect2, varscan2
- COL2A1 | c.2710C>T p.R904C | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs121912882, CM980396, COSV61528961; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COLEC11 | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387907076, CM111429, COSV52592797; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FLCN | c.1285dup p.H429Pfs*27 | Frame Shift Ins (INS) | VAF 18/66 reads (27%) | catalogued as rs80338682; ClinVar: pathogenic; called by mutect2, varscan2
- GATA2 | c.599del p.G200Vfs*18 | Frame Shift Del (DEL) | VAF 37/145 reads (26%) | catalogued as rs768767517, CD141459, COSV62006544, COSV62006643; ClinVar: pathogenic; called by mutect2, varscan2
- GNAQ | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 94/273 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs397514698, CM1412391, COSV54106047, COSV54107425; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LRP2 | c.13139dup p.C4381Mfs*12 | Frame Shift Ins (INS) | VAF 33/165 reads (20%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- SPG11 | c.3075dup p.E1026Rfs*4 | Frame Shift Ins (INS) | VAF 44/211 reads (21%) | catalogued as rs312262752; ClinVar: pathogenic; called by mutect2, varscan2
- TPO | c.2421del p.C808Afs*24 | Frame Shift Del (DEL) | VAF 36/128 reads (28%) | catalogued as rs760307139, COSV100220194; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TSHR | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 142/492 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201889708, COSV53317507; ClinVar: benign / uncertain significance / likely pathogenic; called by muse, varscan2
- A3GALT2 | c.235del p.A79Lfs*27 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | catalogued as rs770563385; called by mutect2, pindel, varscan2
- AAAS | c.839T>C p.V280A | Missense Mutation (SNP) | VAF 68/218 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as COSV99266848; called by muse, mutect2, varscan2
- ABCA7 | c.4634C>T p.A1545V | Missense Mutation (SNP) | VAF 114/376 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54027176; called by muse, mutect2, varscan2
- ABCB1 | c.2296T>A p.S766T | Missense Mutation (SNP) | VAF 98/280 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.798); catalogued as COSV55948438; called by muse, mutect2, varscan2
- ABCE1 | c.1524A>G p.I508M | Missense Mutation (SNP) | VAF 69/236 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.903); catalogued as COSV99668437; called by muse, mutect2, varscan2
- ABHD18 | c.1064T>C p.V355A (on ENST00000398965 / NM_001039717.2; = p.V262A on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV66293522; called by muse, mutect2, varscan2
- ACACB | c.5993A>C p.D1998A | Missense Mutation (SNP) | VAF 232/814 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58131553; called by muse, mutect2, varscan2
- ACAN | c.6917del p.P2306Lfs*10 | Frame Shift Del (DEL) | VAF 19/70 reads (27%) | catalogued as rs777726601; called by mutect2, pindel, varscan2
- ACKR4 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 245/1108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1398393923, COSV51442163; called by muse, mutect2, varscan2
- ACOT9 | c.373+2T>C p.X125_splice | Splice Site (SNP) | VAF 138/455 reads (30%) | catalogued as rs746954701, COSV100321216; called by muse, mutect2, varscan2
- ACRBP | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.005); catalogued as rs1164633243; called by muse, mutect2, varscan2
- ACTA1 | c.911del p.G304Afs*24 | Frame Shift Del (DEL) | VAF 151/512 reads (29%) | catalogued as CD142756, COSV64203291; called by mutect2, pindel, varscan2
- ACTB | c.302A>G p.H101R | Missense Mutation (SNP) | VAF 65/222 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.976); catalogued as rs1341717668, COSV59317914; called by muse, mutect2, varscan2
- ACTL6B | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV50514252; called by muse, mutect2, varscan2
- ACVR2A | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 158/484 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV54020809; called by muse, mutect2, varscan2
- ADAD2 | c.1514G>A p.R505H (on ENST00000315906 / NM_001145400.2; = p.R587H on NM_139174.4) | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.061); catalogued as rs1298845639, COSV51893045; called by muse, mutect2, varscan2
- ADAMTS20 | c.2355del p.E786Kfs*86 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs1177283960; called by mutect2, pindel, varscan2
- ADAMTS4 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs1243925734, COSV63487580; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1826C>T p.P609L | Missense Mutation (SNP) | VAF 311/922 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as COSV54998441; called by muse, mutect2, varscan2
- ADAP1 | c.985A>C p.T329P | Missense Mutation (SNP) | VAF 74/199 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99762843; called by muse, mutect2, varscan2
- ADAP1 | c.577del p.H193Tfs*8 | Frame Shift Del (DEL) | VAF 43/166 reads (26%) | catalogued as rs1284945590; called by mutect2, pindel, varscan2
- ADD3 | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 69/196 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53321538; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 73/270 reads (27%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRG2 | c.2776A>C p.S926R (on ENST00000379869 / NM_001079858.3; = p.S923R on NM_005756.4) | Missense Mutation (SNP) | VAF 167/480 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61338393; called by muse, mutect2, varscan2
- ADGRG3 | c.1070G>A p.G357D | Missense Mutation (SNP) | VAF 119/303 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV59650667; called by muse, mutect2, varscan2
- ADGRV1 | c.13307T>C p.F4436S | Missense Mutation (SNP) | VAF 178/551 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV67982633; called by muse, mutect2, varscan2
- ADH1C | c.665C>A p.A222D | Missense Mutation (SNP) | VAF 370/1423 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV72463427, COSV72463447; called by muse, mutect2, varscan2
- AFAP1 | c.2081C>A p.P694Q | Missense Mutation (SNP) | VAF 137/355 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61794747; called by muse, mutect2, varscan2
- AGRN | c.1345C>T p.Q449* | Nonsense Mutation (SNP) | VAF 23/58 reads (40%) | catalogued as rs1255938863, COSV65068794; called by muse, mutect2, varscan2
- AGRN | c.5693G>A p.R1898H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs142132521; called by muse, mutect2, varscan2
- AHNAK | c.16265T>C p.V5422A | Missense Mutation (SNP) | VAF 69/235 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV99946057; called by muse, varscan2
- AJAP1 | c.902T>C p.L301P | Missense Mutation (SNP) | VAF 147/452 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65450184; called by muse, varscan2
- AJM1 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs375917223, COSV99915504; called by muse, mutect2, varscan2
- AK9 | c.3625del p.R1209Gfs*39 | Frame Shift Del (DEL) | VAF 98/246 reads (40%) | catalogued as rs778351035; called by mutect2, varscan2
- AK9 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs150756404; called by muse, mutect2, varscan2
- AKAP9 | c.1874T>C p.L625P | Missense Mutation (SNP) | VAF 80/215 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62342836; called by muse, mutect2, varscan2
- AKAP9 | c.3128G>C p.G1043A | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.311); catalogued as COSV62342849; called by muse, mutect2, varscan2
- AKNAD1 | c.1711G>T p.D571Y | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV62197029; called by muse, mutect2, varscan2
- AKT1S1 | c.495del p.T166Pfs*87 (on ENST00000344175 / NM_001098633.4; = p.T186Pfs*87 on NM_032375.5) | Frame Shift Del (DEL) | VAF 50/172 reads (29%) | catalogued as rs748776119, COSV59276444; called by mutect2, varscan2
- ALB | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 101/257 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs267600248, COSV55736977, COSV55739910; called by muse, mutect2, varscan2
- ALDH16A1 | c.1382C>T p.S461L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs768690823, COSV53193518; called by muse, mutect2, varscan2
- ALKBH4 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.18); catalogued as COSV52960719; called by muse, mutect2, varscan2
- ANGPTL7 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs753003549, COSV100815803; called by muse, mutect2, varscan2
- ANK3 | c.12420del p.K4140Nfs*15 (on ENST00000280772 / NM_001320874.2; = p.K661Nfs*15 on NM_001149.3) | Frame Shift Del (DEL) | VAF 85/307 reads (28%) | catalogued as rs1466658148; called by mutect2, pindel, varscan2
- ANKLE2 | c.1319A>G p.N440S | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as COSV61708644; called by muse, mutect2, varscan2
- ANKS1A | c.2323G>A p.V775M | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as rs762067571, COSV64459812; called by muse, mutect2, varscan2
- ANKS1A | c.2465G>A p.R822H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780166520, COSV64459819; called by muse, mutect2, varscan2
- ANKS1B | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 70/210 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1359127931, COSV61335488; called by muse, mutect2, varscan2
- ANO8 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as COSV99344161; called by muse, mutect2, varscan2
- ANXA2 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.101); catalogued as rs374077954; called by muse, mutect2, varscan2
- AP3D1 | c.734T>C p.F245S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61426342; called by muse, mutect2, varscan2
- AP3M2 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 180/552 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs151272027; called by muse, varscan2
- AP4B1 | c.958del p.C320Afs*21 | Frame Shift Del (DEL) | VAF 214/824 reads (26%) | catalogued as rs775095423; called by mutect2, pindel, varscan2
- APOB | c.12673G>A p.G4225R | Missense Mutation (SNP) | VAF 98/269 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV51930673; called by muse, mutect2, varscan2
- APOB | c.9016G>T p.G3006C | Missense Mutation (SNP) | VAF 82/238 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1456410181, COSV51930683; called by muse, mutect2, varscan2
- APOBR | c.2030C>T p.A677V (on ENST00000431282; = p.A686V on NM_018690.4) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs779045580; called by muse, mutect2, varscan2
- ARAP1 | c.1869del p.S624Vfs*107 (on ENST00000393609 / NM_001040118.2; = p.S379Vfs*107 on NM_015242.4) | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs751080362, COSV100501527; called by mutect2, varscan2
- ARAP3 | c.2024T>C p.V675A | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.275); catalogued as rs749227449, COSV99499406; called by muse, mutect2, varscan2
- ARFGEF2 | c.848A>G p.D283G | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV64211568; called by muse, mutect2, varscan2
- ARFGEF2 | c.1834C>T p.R612W | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.586); catalogued as rs370911063; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARFGEF3 | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs1175780758, COSV52454502; called by muse, mutect2, varscan2
- ARHGAP24 | c.848T>C p.M283T (on ENST00000395184 / NM_001025616.3; = p.M190T on NM_031305.3) | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV51990111; called by muse, mutect2, varscan2
- ARHGAP33 | c.387dup p.E130Rfs*27 | Frame Shift Ins (INS) | VAF 39/134 reads (29%) | catalogued as rs772293323; called by mutect2, pindel, varscan2
- ARHGAP33 | c.1522G>A p.V508I | Missense Mutation (SNP) | VAF 139/397 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.211); catalogued as rs535794132, COSV50121111; called by muse, mutect2, varscan2
- ARHGAP6 | c.2635C>T p.R879W (on ENST00000337414 / NM_013427.3; = p.R676W on NM_013423.3) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.965); catalogued as COSV57293977; called by muse, mutect2, varscan2
- ARHGDIB | c.515A>G p.Y172C | Missense Mutation (SNP) | VAF 128/456 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56762873; called by muse, mutect2, varscan2
- ARHGEF1 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 86/234 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as rs782343511, COSV61527129; called by muse, mutect2, varscan2
- ARHGEF11 | c.1670del p.P557Lfs*9 | Frame Shift Del (DEL) | VAF 51/159 reads (32%) | catalogued as COSV63816428; called by mutect2, pindel, varscan2
- ARHGEF18 | c.1300C>T p.R434C (on ENST00000359920 / NM_001130955.2; = p.R330C on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/231 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs756499530, COSV60468522, COSV60474868; called by muse, mutect2, varscan2
- ARHGEF18 | c.2086A>G p.R696G (on ENST00000359920 / NM_001130955.2; = p.R592G on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV100149142; called by muse, mutect2, varscan2
- ARHGEF26 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs994217053, COSV62845270; called by muse, varscan2
- ARHGEF28 | c.1219T>C p.C407R | Missense Mutation (SNP) | VAF 93/272 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs767417665, COSV55252489; called by muse, mutect2, varscan2
- ARHGEF28 | c.2968C>T p.R990* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as rs771514690, COSV55252501; called by muse, mutect2, varscan2
- ARHGEF7 | c.67dup p.T23Nfs*86 (on ENST00000375741 / NM_001113511.2; = p.T23Nfs*65 on NM_145735.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 34/108 reads (31%) | catalogued as rs754827718; called by mutect2, varscan2
- ARID2 | c.3365T>C p.V1122A | Missense Mutation (SNP) | VAF 111/337 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.097); catalogued as rs1476958272, COSV100535583; called by muse, mutect2, varscan2
- ARL6IP6 | c.400+2T>C p.X134_splice | Splice Site (SNP) | VAF 120/365 reads (33%) | catalogued as COSV58442484; called by muse, mutect2, varscan2
- ARNTL2 | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 100/325 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.231); catalogued as rs11049005; called by muse, mutect2, varscan2
- ARRDC2 | c.316T>C p.F106L | Missense Mutation (SNP) | VAF 73/242 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV55843990; called by muse, mutect2, varscan2
- ARVCF | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs761726212, COSV99599002; called by muse, mutect2, varscan2
- ASB11 | c.95dup p.L32Ffs*14 | Frame Shift Ins (INS) | VAF 52/192 reads (27%) | catalogued as rs777775669; called by mutect2, varscan2
- ASB13 | c.361del p.L121Cfs*6 | Frame Shift Del (DEL) | VAF 35/186 reads (19%) | catalogued as COSV63090510; called by mutect2, pindel, varscan2
- ASH1L | c.6809A>G p.Q2270R (on ENST00000368346 / NM_001366177.2; = p.Q2265R on NM_018489.3) | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.928); catalogued as COSV64206851; called by muse, varscan2
- ASPN | c.241T>C p.C81R | Missense Mutation (SNP) | VAF 100/334 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65016025; called by muse, varscan2
- ASTN2 | c.2572C>T p.R858W (on ENST00000313400 / NM_001365069.1; = p.R807W on NM_014010.5) | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754101258, COSV57766765; called by muse, mutect2, varscan2
- ASTN2 | c.1675G>T p.G559* (on ENST00000313400 / NM_001365069.1; = p.G508* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 77/240 reads (32%) | catalogued as COSV100525292, COSV57775594; called by muse, mutect2, varscan2
- ASTN2 | c.1579G>A p.D527N (on ENST00000313400 / NM_001365069.1; = p.D476N on NM_014010.5) | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs976057171, COSV57747261; called by muse, mutect2, varscan2
- ASXL1 | c.2535dup p.S846Qfs*5 | Frame Shift Ins (INS) | VAF 324/1164 reads (28%) | catalogued as rs750170870; called by mutect2, pindel, varscan2
- ATG14 | c.1190T>C p.V397A | Missense Mutation (SNP) | VAF 96/276 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV55956052; called by muse, mutect2, varscan2
- ATG7 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 133/443 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs772454167, COSV61611198; called by muse, mutect2, varscan2
- ATM | c.6031A>G p.S2011G | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV53736048; called by muse, varscan2
- ATP10A | c.2411C>T p.A804V | Missense Mutation (SNP) | VAF 94/304 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs763990614, COSV63515700; called by muse, mutect2, varscan2
- ATP12A | c.1705+2T>C p.X569_splice | Splice Site (SNP) | VAF 51/153 reads (33%) | catalogued as COSV99517151; called by muse, mutect2, varscan2
- ATP2B3 | c.3317G>A p.R1106Q | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as rs1557017728, COSV54843785; called by muse, mutect2, varscan2
- ATP2B3 | c.3524del p.P1175Rfs*12 | Frame Shift Del (DEL) | VAF 122/455 reads (27%) | catalogued as rs782513834; called by mutect2, varscan2
- ATP2C2 | c.1913C>T p.A638V | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV52294282; called by muse, mutect2, varscan2
- ATP4A | c.2665T>C p.W889R | Missense Mutation (SNP) | VAF 70/275 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99382239; called by muse, mutect2, varscan2
- ATP8A2 | c.1712+2T>C p.X571_splice | Splice Site (SNP) | VAF 50/178 reads (28%) | catalogued as COSV54945585; called by muse, mutect2, varscan2
- ATP8B1 | c.2609C>A p.P870H | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52174207; called by muse, mutect2, varscan2
- ATP8B2 | c.536C>T p.A179V (on ENST00000672630; = p.A146V on NM_001005855.2) | Missense Mutation (SNP) | VAF 82/313 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.244); catalogued as rs776939812, COSV59245184; called by muse, mutect2, varscan2
- ATPSCKMT | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 103/395 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs745363656; called by muse, mutect2, varscan2
- ATXN2L | c.54del p.T19Rfs*119 | Frame Shift Del (DEL) | VAF 25/92 reads (27%) | catalogued as rs770993364; called by mutect2, pindel, varscan2
- AUTS2 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 130/385 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV61392101, COSV61392824; called by muse, mutect2, varscan2
- AXL | c.1517G>A p.R506H (on ENST00000301178 / NM_021913.5; = p.R497H on NM_001699.6) | Missense Mutation (SNP) | VAF 172/499 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1162584880, COSV56566309; called by muse, mutect2, varscan2
- B4GALNT2 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV55925515; called by muse, mutect2, varscan2
- BABAM2 | c.788A>G p.Y263C | Missense Mutation (SNP) | VAF 109/294 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV59620146; called by muse, mutect2, varscan2
- BAG6 | c.1169dup p.T391Nfs*29 | Frame Shift Ins (INS) | VAF 74/244 reads (30%) | catalogued as rs745882580; called by mutect2, varscan2
- BARD1 | c.1788del p.K596Nfs*9 | Frame Shift Del (DEL) | VAF 58/634 reads (9%) | catalogued as COSV53612208; called by mutect2, pindel
- BCAR1 | c.890T>G p.L297R | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV99366137; called by muse, mutect2, varscan2
- BCAR1 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1281183894, COSV50780130; called by muse, mutect2, varscan2
- BCOR | c.1404C>A p.H468Q | Missense Mutation (SNP) | VAF 64/215 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV100653002; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 48/174 reads (28%) | catalogued as rs768244116; called by mutect2, varscan2
- BEND3 | c.2206G>A p.V736M | Missense Mutation (SNP) | VAF 69/194 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1554231295, COSV64682447; called by muse, mutect2, varscan2
- BEND3 | c.793dup p.D265Gfs*95 | Frame Shift Ins (INS) | VAF 17/81 reads (21%) | catalogued as rs782111679; called by mutect2, varscan2
- BEST2 | c.152+2T>G p.X51_splice | Splice Site (SNP) | VAF 33/86 reads (38%) | catalogued as COSV99244272; called by muse, mutect2, varscan2
- BLM | c.563A>G p.K188R | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs907949967, COSV100757025; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP10 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 79/422 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.6); catalogued as COSV54896407; called by muse, mutect2, varscan2
- BMP6 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 71/180 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.072); catalogued as rs577694907, COSV51663347; called by muse, mutect2, varscan2
- BMPER | c.927+2T>C p.X309_splice | Splice Site (SNP) | VAF 155/401 reads (39%) | catalogued as COSV51814978; called by muse, mutect2, varscan2
- BMPR2 | c.464T>A p.L155* | Nonsense Mutation (SNP) | VAF 149/420 reads (35%) | catalogued as COSV65808473; called by muse, mutect2, varscan2
- BMPR2 | c.690del p.V231Cfs*21 | Frame Shift Del (DEL) | VAF 85/278 reads (31%) | catalogued as COSV65810054; called by mutect2, pindel, varscan2
- BMPR2 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 70/236 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.7); catalogued as rs201440272, COSV65808479; called by muse, mutect2, varscan2
- BNC2 | c.829A>G p.K277E | Missense Mutation (SNP) | VAF 16/522 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1336792156, COSV66150799; called by muse, mutect2
- BNIP3 | c.222G>T p.M74I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as COSV100893173; called by muse, mutect2, varscan2
- BNIP5 | c.1702del p.Y568Tfs*12 | Frame Shift Del (DEL) | VAF 53/180 reads (29%) | catalogued as COSV71325486; called by mutect2, pindel, varscan2
- BOD1L1 | c.8392G>A p.A2798T | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs774507896, COSV50009015; called by muse, mutect2, varscan2
- BRIP1 | c.1027C>A p.L343M | Missense Mutation (SNP) | VAF 197/591 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV51997190; called by muse, mutect2, varscan2
- BRSK2 | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV57542104; called by muse, mutect2, varscan2
- BRWD1 | c.6809G>A p.R2270Q | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.766); catalogued as rs1387048628, COSV59000046; called by muse, mutect2, varscan2
- BSN | c.10609A>G p.M3537V | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs778906963, COSV99607553; called by muse, mutect2, varscan2
- BTBD17 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1329577813; called by muse, mutect2, varscan2
- BTNL9 | c.167A>G p.E56G | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1396382490, COSV59794955; called by muse, mutect2, varscan2
- C10orf120 | c.898G>T p.D300Y | Missense Mutation (SNP) | VAF 182/494 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV61491793, COSV61492605; called by muse, mutect2, varscan2
- C10orf90 | c.395del p.G132Afs*76 | Frame Shift Del (DEL) | VAF 26/112 reads (23%) | catalogued as rs756932045; called by mutect2, pindel, varscan2
- C17orf75 | c.469G>T p.G157W | Missense Mutation (SNP) | VAF 195/628 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56752576; called by muse, mutect2, varscan2
- C1QL3 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.09); catalogued as COSV54348460; called by muse, mutect2, varscan2
- C1QTNF3 | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.549); catalogued as COSV51468193; called by muse, mutect2, varscan2
- C1orf159 | c.602A>G p.Q201R (on ENST00000379339 / NM_001330306.2; = p.Q165R on NM_017891.5) | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV99618241; called by muse, mutect2, varscan2
- C2orf16 | c.4820G>A p.R1607H | Missense Mutation (SNP) | VAF 164/430 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1047397156, COSV62674761; called by muse, mutect2, varscan2
- C4orf46 | c.292T>C p.W98R | Missense Mutation (SNP) | VAF 130/355 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs765140061, COSV57014581; called by muse, mutect2, varscan2
- C7orf50 | c.215del p.K72Rfs*87 | Frame Shift Del (DEL) | VAF 24/95 reads (25%) | catalogued as COSV62475944; called by mutect2, pindel, varscan2
- C7orf61 | c.620A>G p.*207Wext*10 | Nonstop Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV60092617; called by muse, mutect2, varscan2
- C8B | c.100del p.R34Gfs*27 | Frame Shift Del (DEL) | VAF 69/303 reads (23%) | catalogued as COSV64779890; called by mutect2, pindel, varscan2
- CABLES1 | c.847C>T p.R283W (on ENST00000256925 / NM_001100619.2; = p.R18W on NM_138375.2) | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs529420681, COSV56932228; called by muse, mutect2, varscan2
- CABLES1 | c.1568T>C p.M523T (on ENST00000256925 / NM_001100619.2; = p.M258T on NM_138375.2) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV56932238; called by muse, mutect2, varscan2
- CACNA1B | c.2417G>A p.R806Q | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.397); catalogued as rs890458453; called by muse, mutect2, varscan2
- CACNA1I | c.2524T>C p.F842L | Missense Mutation (SNP) | VAF 97/292 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV100361999, COSV60809896; called by muse, mutect2, varscan2
- CACNA1I | c.5993G>A p.R1998Q | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs762336883, COSV60804825; called by muse, mutect2, varscan2
- CACNB1 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV59998500; called by muse, mutect2, varscan2
- CACNG2 | c.325A>G p.I109V | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs1464499620; called by muse, mutect2, varscan2
- CACUL1 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 112/400 reads (28%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.014); catalogued as COSV60993654, COSV60994352; called by muse, mutect2, varscan2
- CADM1 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 111/355 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs768807528, COSV59002182; called by muse, mutect2, varscan2
- CAMK2G | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 81/240 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV59481051; called by muse, mutect2, varscan2
- CAND1 | c.46A>G p.T16A | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.415); catalogued as COSV73338853; called by muse, mutect2, varscan2
- CAPN2 | c.729+1G>A p.X243_splice | Splice Site (SNP) | VAF 75/222 reads (34%) | catalogued as rs549405629, COSV54335443; called by muse, mutect2, varscan2
- CAPS2 | c.1373A>G p.D458G | Missense Mutation (SNP) | VAF 140/413 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60824759; called by muse, mutect2, varscan2
- CARD10 | c.1578del p.S527Vfs*31 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as rs35832225; called by mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 99/198 reads (50%) | catalogued as rs762770988, COSV62756627; called by mutect2, pindel, varscan2
- CARNS1 | c.2423A>G p.Q808R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.715); catalogued as COSV100321808; called by muse, mutect2, varscan2
- CASP8AP2 | c.821A>G p.E274G | Missense Mutation (SNP) | VAF 218/653 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV52746193; called by muse, mutect2, varscan2
- CASZ1 | c.4022G>C p.G1341A | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.553); catalogued as rs376223327, COSV59734162; called by muse, mutect2, varscan2
- CBARP | c.1108del p.D370Mfs*37 (on ENST00000382477; = p.D350Mfs*40 on NM_152769.3) | Frame Shift Del (DEL) | VAF 72/240 reads (30%) | catalogued as COSV99289301; called by pindel, varscan2
- CBX8 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 276/755 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53936060; called by muse, mutect2, varscan2
- CBY2 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.555); catalogued as rs1371744667, COSV100137492; called by muse, mutect2, varscan2
- CCAR1 | c.2705A>G p.Y902C | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.319); catalogued as rs755031358; called by muse, mutect2, varscan2
- CCDC190 | c.36G>T p.K12N | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV63362709; called by muse, varscan2
- CCDC190 | c.27A>C p.Q9H | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV63362716; called by muse, varscan2
- CCDC88B | c.1915del p.W639Gfs*3 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | catalogued as COSV57265608; called by mutect2, varscan2
- CCDC93 | c.335A>T p.D112V | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60120630; called by muse, mutect2, varscan2
- CCDC9B | c.294del p.M99Wfs*3 | Frame Shift Del (DEL) | VAF 114/409 reads (28%) | catalogued as rs765438623; called by mutect2, pindel, varscan2
- CCNF | c.1391A>G p.H464R | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); catalogued as COSV53539117; called by muse, mutect2, varscan2
- CCNK | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs749729510, COSV66274837; called by muse, varscan2
- CCR10 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs1230864047; called by mutect2, varscan2
- CCSAP | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 112/279 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1414465475, COSV52909113; called by muse, mutect2, varscan2
- CD200R1L | c.55A>G p.S19G | Missense Mutation (SNP) | VAF 92/321 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV68004039; called by muse, mutect2, varscan2
- CD27 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 139/489 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.938); catalogued as rs763617266, COSV56949851; called by muse, mutect2, varscan2
- CD38 | c.138G>A p.W46* | Nonsense Mutation (SNP) | VAF 72/297 reads (24%) | catalogued as COSV56889242; called by muse, mutect2, varscan2
- CD52 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 72/226 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.666); catalogued as rs141117966; called by muse, mutect2, varscan2
- CD58 | c.308A>G p.Y103C | Missense Mutation (SNP) | VAF 77/248 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65664727; called by muse, mutect2, varscan2
- CDC23 | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 78/250 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV67508357, COSV67508376; called by muse, mutect2, varscan2
- CDH22 | c.1735del p.I579Sfs*4 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | catalogued as COSV64837066; called by mutect2, pindel, varscan2
- CDH23 | c.7632G>T p.L2544F | Missense Mutation (SNP) | VAF 85/296 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs775191895, COSV56456099; called by muse, mutect2, varscan2
- CDHR1 | c.89A>G p.N30S | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs757172364, COSV60561247; called by muse, mutect2, varscan2
- CDHR3 | c.1433C>T p.T478I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs1407144190, COSV58415571; called by muse, mutect2
- CDK1 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.876); catalogued as rs45540532, COSV100358778; called by muse, mutect2, varscan2
- CDK14 | c.805del p.E269Sfs*2 (on ENST00000380050 / NM_001287135.2; = p.E251Sfs*2 on NM_012395.3) | Frame Shift Del (DEL) | VAF 115/409 reads (28%) | catalogued as COSV56052544; called by mutect2, pindel, varscan2
- CDK5RAP2 | c.998del p.K333Rfs*76 | Frame Shift Del (DEL) | VAF 66/237 reads (28%) | catalogued as rs973156155; called by mutect2, pindel, varscan2
- CELSR3 | c.6965C>A p.P2322H | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV50845960; called by muse, mutect2, varscan2
- CENPE | c.3703G>T p.E1235* | Nonsense Mutation (SNP) | VAF 100/314 reads (32%) | catalogued as COSV54379091; called by muse, mutect2, varscan2
- CEP126 | c.352T>A p.F118I | Missense Mutation (SNP) | VAF 63/176 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54823687; called by muse, mutect2, varscan2
- CEP164 | c.1482del p.Q496Rfs*97 | Frame Shift Del (DEL) | VAF 10/21 reads (48%) | catalogued as rs755923652, COSV54039972; called by mutect2, pindel, varscan2
- CEP250 | c.670A>G p.T224A | Missense Mutation (SNP) | VAF 144/380 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs1407275854, COSV100698780; called by muse, mutect2, varscan2
- CEP250 | c.2698G>A p.A900T | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.781); catalogued as COSV100699200, COSV61169197; called by muse, varscan2
- CEP250 | c.2726G>A p.R909Q | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.086); catalogued as rs775429730, COSV61169204; called by muse, varscan2
- CEP290 | c.5327T>C p.V1776A | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100468019; called by muse, varscan2
- CEP68 | c.2135A>C p.K712T | Missense Mutation (SNP) | VAF 100/292 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV53124224; called by muse, mutect2, varscan2
- CES3 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 97/343 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs71649615; called by muse, mutect2, varscan2
- CES5A | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761721054, COSV51865340; called by muse, mutect2, varscan2
- CFAP100 | c.1668G>T p.Q556H | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.286); catalogued as COSV61502766; called by muse, mutect2, varscan2
- CFAP70 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 91/251 reads (36%) | catalogued as COSV60282234; called by muse, mutect2, varscan2
- CFC1 | c.241G>T p.G81* | Nonsense Mutation (SNP) | VAF 20/114 reads (18%) | catalogued as COSV52090420; called by muse, varscan2
- CFH | c.2488C>T p.R830W | Missense Mutation (SNP) | VAF 84/302 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs62641696, COSV66408840; called by muse, mutect2, varscan2
- CGNL1 | c.1772G>A p.R591Q | Missense Mutation (SNP) | VAF 68/247 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs778457143, COSV55565656; called by muse, mutect2, varscan2
- CHD7 | c.2612A>G p.E871G | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV101418046, COSV71113532; called by muse, mutect2, varscan2
- CHD7 | c.8267C>T p.T2756M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs757521506, CD112416; called by muse, mutect2, varscan2
- CHD8 | c.4948G>A p.A1650T (on ENST00000646647 / NM_001170629.2; = p.A1371T on NM_020920.4) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV100783807; called by muse, mutect2, varscan2
- CHMP6 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs913344986, COSV57327068; called by muse, mutect2, varscan2
- CHN1 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 125/404 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs373546784; called by muse, mutect2, varscan2
- CHRD | c.310C>G p.P104A | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV52606900; called by muse, mutect2, varscan2
- CHRNA1 | c.367del p.I123Ffs*67 (on ENST00000261007 / NM_001039523.3; = p.I98Ffs*67 on NM_000079.4) | Frame Shift Del (DEL) | VAF 94/315 reads (30%) | catalogued as rs753250273; called by mutect2, pindel, varscan2
- CHRNA4 | c.1432G>A p.V478M | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.309); catalogued as COSV64719005; called by muse, mutect2, varscan2
- CHST1 | c.470G>A p.S157N | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100346066; called by muse, varscan2
- CIC | c.2492C>T p.T831M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV50546523; called by muse, mutect2, varscan2
- CIITA | c.1138C>T p.R380W | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs750567359, COSV60855892, COSV60856029; called by muse, mutect2, varscan2
- CISD2 | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as COSV56765705; called by muse, mutect2, varscan2
- CIT | c.4534G>A p.E1512K | Missense Mutation (SNP) | VAF 126/355 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs781056753, COSV55859602; called by muse, mutect2, varscan2
- CLCN6 | c.1834G>A p.V612I | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV56739138, COSV56742123; called by muse, mutect2, varscan2
- CLEC16A | c.383T>C p.V128A | Missense Mutation (SNP) | VAF 72/214 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV68498962; called by muse, mutect2, varscan2
- CLEC16A | c.2650G>A p.V884M | Missense Mutation (SNP) | VAF 71/194 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as rs74163624, COSV55489300, COSV55490189; called by muse, mutect2, varscan2
- CLEC4M | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 106/287 reads (37%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.983); catalogued as rs375821664; called by muse, mutect2, varscan2
- CLPTM1 | c.656A>G p.D219G | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV61611594; called by muse, mutect2, varscan2
- CMTM8 | c.77G>A p.S26N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV56776532; called by muse, varscan2
- CMTR2 | c.1798C>T p.R600* | Nonsense Mutation (SNP) | VAF 64/206 reads (31%) | catalogued as rs200221398, COSV57602756; called by muse, mutect2, varscan2
- CMTR2 | c.551T>G p.L184R | Missense Mutation (SNP) | VAF 206/577 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.393); catalogued as COSV57603077; called by muse, mutect2, varscan2
- CNBD1 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs747773867, COSV73072467; called by muse, mutect2, varscan2
- CNKSR1 | c.1535dup p.P513Tfs*9 (on ENST00000374253 / NM_001297647.2; = p.P506Tfs*9 on NM_006314.3) | Frame Shift Ins (INS) | VAF 58/192 reads (30%) | catalogued as rs753922055; called by mutect2, varscan2
- CNTN2 | c.1270G>A p.V424M | Missense Mutation (SNP) | VAF 165/486 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.222); catalogued as rs548252200, COSV59349297; called by muse, mutect2, varscan2
- CNTN6 | c.2678dup p.V894Sfs*25 | Frame Shift Ins (INS) | VAF 164/643 reads (26%) | catalogued as rs1415730148; called by mutect2, pindel, varscan2
- CNTNAP5 | c.194G>A p.G65D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70480855; called by muse, mutect2, varscan2
- COBL | c.121dup p.H41Pfs*31 | Frame Shift Ins (INS) | VAF 22/92 reads (24%) | catalogued as rs778516787; called by mutect2, varscan2
- COL12A1 | c.8098G>A p.A2700T | Missense Mutation (SNP) | VAF 130/449 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779479987, COSV59392888, COSV59407435; called by muse, mutect2, varscan2
- COL22A1 | c.2014G>A p.G672S | Missense Mutation (SNP) | VAF 65/234 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs756630962, COSV57324838; called by muse, mutect2, varscan2
- COL23A1 | c.958A>G p.K320E | Missense Mutation (SNP) | VAF 36/1044 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as COSV101179588; called by muse, mutect2
- COL4A2 | c.5111G>A p.R1704H | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747313370, COSV64626923; called by muse, mutect2, varscan2
- COL4A3 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as rs773914532, COSV67414589; called by muse, mutect2, varscan2
- COL6A3 | c.3371C>T p.A1124V | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs374447921, COSV99799860; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- COL7A1 | c.8774G>A p.C2925Y | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56476299; called by muse, mutect2, varscan2
- COL7A1 | c.1277T>C p.L426P | Missense Mutation (SNP) | VAF 76/279 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.977); catalogued as COSV60393634; called by muse, mutect2, varscan2
- COL8A2 | c.684dup p.G229Rfs*25 | Frame Shift Ins (INS) | VAF 14/44 reads (32%) | catalogued as rs769991029; called by mutect2, varscan2
- COL9A3 | c.1739dup p.G581Wfs*20 | Frame Shift Ins (INS) | VAF 15/59 reads (25%) | catalogued as rs764718355; called by mutect2, pindel, varscan2
- COMMD10 | c.58T>C p.S20P | Missense Mutation (SNP) | VAF 106/358 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV57235525; called by muse, varscan2
- COQ2 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.614); catalogued as COSV61021322; called by muse, mutect2, varscan2
- CORIN | c.2723T>A p.V908D | Missense Mutation (SNP) | VAF 90/281 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99903102; called by muse, mutect2, varscan2
- CORO7 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs200117600, COSV99228160, COSV99228274; called by muse, varscan2
- CPQ | c.1016G>A p.G339D | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55142186; called by muse, mutect2, varscan2
- CPS1 | c.3462G>T p.E1154D | Missense Mutation (SNP) | VAF 96/287 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.801); catalogued as COSV51806479, COSV51812131; called by muse, mutect2, varscan2
- CPT1C | c.1160G>T p.R387M | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54918519; called by muse, mutect2, varscan2
- CPZ | c.769A>G p.M257V (on ENST00000360986 / NM_001014447.3; = p.M246V on NM_003652.3) | Missense Mutation (SNP) | VAF 78/239 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV59922379; called by muse, mutect2, varscan2
- CREBBP | c.5204C>T p.T1735M | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs1064793090, CM104888, COSV52119093; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRISP1 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 92/317 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.521); catalogued as COSV100236661, COSV59993214; called by muse, mutect2, varscan2
- CRLF3 | c.1207C>T p.R403* | Nonsense Mutation (SNP) | VAF 77/219 reads (35%) | catalogued as COSV60835530; called by muse, mutect2, varscan2
- CRNN | c.1403A>G p.Q468R | Missense Mutation (SNP) | VAF 83/233 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV55121445; called by muse, mutect2, varscan2
- CRTC1 | c.1713del p.S572Afs*6 | Frame Shift Del (DEL) | VAF 96/268 reads (36%) | catalogued as rs769538822; called by mutect2, varscan2
- CRY2 | c.1060A>G p.T354A | Missense Mutation (SNP) | VAF 76/273 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101314560; called by muse, varscan2
- CRYBB1 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.32); catalogued as rs776964678, COSV53232899; called by muse, mutect2, varscan2
- CSF1 | c.205T>C p.F69L | Missense Mutation (SNP) | VAF 150/513 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60032616; called by muse, mutect2, varscan2
- CSF1R | c.1626+2T>C p.X542_splice | Splice Site (SNP) | VAF 38/144 reads (26%) | catalogued as COSV99641100; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 108/352 reads (31%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSRNP3 | c.1444C>T p.R482* | Nonsense Mutation (SNP) | VAF 44/117 reads (38%) | catalogued as rs199561929, COSV58776975, COSV58780852; called by muse, mutect2, varscan2
- CTCFL | c.75del p.G26Afs*2 | Frame Shift Del (DEL) | VAF 358/1392 reads (26%) | catalogued as rs1224759530; called by pindel, varscan2
- CTIF | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs775953061, COSV99837025; called by muse, mutect2, varscan2
- CTNNA2 | c.2659T>G p.S887A (on ENST00000402739 / NM_001282597.3; = p.S839A on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 157/496 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58144745; called by muse, mutect2, varscan2
- CTNND2 | c.2765A>G p.D922G | Missense Mutation (SNP) | VAF 90/294 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV58875074; called by muse, mutect2, varscan2
- CTNND2 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs778030487, COSV58867380; called by muse, mutect2, varscan2
- CTR9 | c.1880G>A p.R627H | Missense Mutation (SNP) | VAF 100/378 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs1413777307, COSV63728254; called by muse, mutect2, varscan2
- CTR9 | c.2880_2882del p.R962del | In Frame Del (DEL) | VAF 66/200 reads (33%) | catalogued as rs968571283; called by pindel, varscan2
- CUTC | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 150/497 reads (30%) | catalogued as rs867595661, COSV65081673; called by muse, mutect2, varscan2
- CUX2 | c.3121G>A p.V1041M | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs755408839, COSV55628672; called by muse, mutect2, varscan2
- CXCR2 | c.993A>G p.I331M | Missense Mutation (SNP) | VAF 98/284 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV59280287; called by muse, mutect2, varscan2
- CXCR3 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.058); catalogued as rs905571589, COSV65461770; called by muse, mutect2, varscan2
- CYP17A1 | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1250463562, CM920226, COSV64004840; called by muse, mutect2, varscan2
- CYP27B1 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 68/219 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768857789, COSV56984418; called by muse, mutect2, varscan2
- CYP7B1 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 61/199 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1410531135, COSV59584668, COSV59594434; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYSLTR1 | c.697G>T p.G233* | Nonsense Mutation (SNP) | VAF 74/254 reads (29%) | catalogued as COSV64819797, COSV64820875; called by muse, varscan2
- DAAM1 | c.1488G>T p.K496N | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV62835380; called by muse, mutect2, varscan2
- DBX2 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.198); catalogued as COSV100224224; called by mutect2, varscan2
- DCAF12L2 | c.126G>T p.Q42H | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT tolerated (0.19); PolyPhen benign (0.188); catalogued as COSV63580954; called by muse, mutect2, varscan2
- DCAF5 | c.2468G>T p.R823M | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV58459583; called by muse, mutect2, varscan2
- DCLRE1C | c.207_209del p.L70del | In Frame Del (DEL) | VAF 40/155 reads (26%) | catalogued as rs753202682; called by pindel, varscan2
- DCST1 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1281341389, COSV55057752; called by muse, mutect2
- DCTN1 | c.3518G>A p.R1173H | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs980920477, COSV62620128; called by muse, mutect2, varscan2
- DDB1 | c.685dup p.A229Gfs*15 | Frame Shift Ins (INS) | VAF 24/77 reads (31%) | catalogued as rs757472327; called by mutect2, varscan2
- DDIT4L | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 99/302 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs183155282; called by muse, mutect2, varscan2
- DDX11 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs148220883, COSV52502131; called by muse, mutect2, varscan2
- DDX11 | c.1862del p.G621Vfs*32 | Frame Shift Del (DEL) | VAF 21/199 reads (11%) | catalogued as rs766120336; called by mutect2, pindel, varscan2
- DDX11 | c.2170G>T p.G724C | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52502163, COSV99298823; called by muse, mutect2, varscan2
- DDX54 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs201173369, COSV58372759; called by muse, mutect2, varscan2
- DDX55 | c.239dup p.S81Efs*48 | Frame Shift Ins (INS) | VAF 24/127 reads (19%) | catalogued as rs762423517; called by mutect2, pindel, varscan2
- DDX59 | c.1294A>G p.K432E | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV58751329; called by muse, mutect2, varscan2
- DES | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.874); catalogued as COSV64660147; called by muse, mutect2, varscan2
- DGKD | c.2564del p.G855Vfs*48 (on ENST00000264057 / NM_152879.3; = p.G811Vfs*48 on NM_003648.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 119/465 reads (26%) | catalogued as rs35538077; called by mutect2, pindel, varscan2
- DGKK | c.371A>C p.E124A | Missense Mutation (SNP) | VAF 115/325 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV101052907; called by muse, mutect2, varscan2
- DHX34 | c.2686G>A p.V896I | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.218); catalogued as rs756746132, COSV60894984; called by muse, mutect2, varscan2
- DHX37 | c.1136T>C p.V379A | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.142); catalogued as COSV58133347; called by muse, mutect2, varscan2
- DIP2B | c.4471G>A p.A1491T | Missense Mutation (SNP) | VAF 91/270 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.07); catalogued as rs777261445, COSV56581591; called by muse, mutect2, varscan2
- DISP2 | c.151A>C p.S51R | Missense Mutation (SNP) | VAF 165/603 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.996); catalogued as rs750749839, COSV99139759; called by muse, mutect2, varscan2
- DKK1 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138915253; called by muse, mutect2, varscan2
- DLGAP3 | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs142976280; called by muse, mutect2, varscan2
- DLK1 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs767836232, COSV57991140; called by muse, mutect2, varscan2
- DLST | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 166/546 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV99471827; called by muse, mutect2, varscan2
- DLX2 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 80/263 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200908537, COSV52231832, COSV52232028; called by muse, varscan2
- DMAP1 | c.904C>G p.P302A | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as COSV60000305; called by muse, mutect2, varscan2
- DMXL2 | c.2972T>C p.I991T | Missense Mutation (SNP) | VAF 139/412 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV51843626; called by muse, mutect2, varscan2
- DMXL2 | c.2512G>A p.A838T | Missense Mutation (SNP) | VAF 253/849 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.454); catalogued as rs199866251; called by muse, mutect2, varscan2
- DNAH10 | c.8734A>G p.I2912V (on ENST00000409039; = p.I2851V on NM_207437.3) | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV68991111; called by muse, mutect2, varscan2
- DNAH17 | c.6347A>G p.E2116G | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101101650; called by muse, mutect2, varscan2
- DNAH2 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 86/241 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.31); catalogued as rs768754911, COSV50015282; called by muse, mutect2, varscan2
- DNAH2 | c.12917G>A p.S4306N | Missense Mutation (SNP) | VAF 416/1316 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV66718269; called by muse, varscan2
- DNAH5 | c.12829T>C p.F4277L | Missense Mutation (SNP) | VAF 84/250 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.282); catalogued as COSV54216036; called by muse, mutect2, varscan2
- DNAH7 | c.4181C>T p.A1394V | Missense Mutation (SNP) | VAF 77/264 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56758708; called by muse, mutect2, varscan2
- DNAH8 | c.4837G>T p.D1613Y | Missense Mutation (SNP) | VAF 81/279 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59436372; called by muse, mutect2, varscan2
- DNAH8 | c.4838A>T p.D1613V | Missense Mutation (SNP) | VAF 80/280 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59436397, COSV59438542; called by muse, mutect2, varscan2
- DNAH8 | c.9197G>A p.R3066H | Missense Mutation (SNP) | VAF 81/224 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs540958336, COSV100543719; called by muse, mutect2, varscan2
- DNAH9 | c.7111G>T p.E2371* | Nonsense Mutation (SNP) | VAF 58/170 reads (34%) | catalogued as COSV52343834, COSV52380747; called by muse, mutect2, varscan2
- DNAJB2 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 59/237 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs747378005, COSV60676729; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNM2 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as COSV99139013; called by muse, mutect2, varscan2
- DNTTIP1 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs767661063, COSV54755204; called by muse, mutect2, varscan2
- DOCK7 | c.2765A>C p.K922T | Missense Mutation (SNP) | VAF 83/230 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV52001321; called by muse, mutect2, varscan2
- DOK4 | c.190A>G p.N64D | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as COSV99538238; called by muse, mutect2, varscan2
- DPT | c.382T>C p.W128R | Missense Mutation (SNP) | VAF 50/259 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199993492, COSV63189759; called by muse, mutect2, varscan2
- DPYD | c.1010T>C p.V337A | Missense Mutation (SNP) | VAF 93/291 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV64594413; called by muse, mutect2, varscan2
- DPYSL2 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.222); catalogued as rs751569597, COSV60785726; called by muse, varscan2
- DPYSL5 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 115/392 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as rs747513449, COSV56510456; called by muse, mutect2, varscan2
- DSCAML1 | c.1565C>T p.S522L (on ENST00000321322; = p.S462L on NM_020693.4) | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.396); catalogued as rs935338538, COSV58387224; called by muse, varscan2
- DSEL | c.970T>C p.F324L | Missense Mutation (SNP) | VAF 120/373 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs745761044, COSV59490524; called by muse, mutect2, varscan2
- DST | c.3860G>A p.G1287D (on ENST00000361203 / NM_001374722.1; = p.G961D on NM_001723.6) | Missense Mutation (SNP) | VAF 78/240 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs770079828, COSV55006966; called by muse, varscan2
- DSTYK | c.938T>C p.L313P | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65686031; called by muse, mutect2, varscan2
- DYDC2 | c.500A>G p.H167R | Missense Mutation (SNP) | VAF 41/792 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.043); catalogued as COSV55471705, COSV55472511; called by muse, mutect2
- DYNC2I1 | c.2887T>C p.S963P | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV101337620; called by muse, mutect2, varscan2
- DYRK1B | c.1633del p.Q545Sfs*19 | Frame Shift Del (DEL) | VAF 24/103 reads (23%) | catalogued as rs775499198; called by mutect2, pindel, varscan2
- DYSF | c.2263G>A p.A755T | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50476650, COSV99245007; called by muse, mutect2, varscan2
- EBF3 | c.1374C>T p.V458= (on ENST00000355311 / NM_001375392.1; = p.V449= on NM_001005463.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 90/186 reads (48%) | catalogued as rs751553455, COSV100799071; called by muse, mutect2, varscan2
- ECEL1 | c.665T>C p.V222A | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs766643692, COSV100458510; called by muse, mutect2, varscan2
- ECI1 | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs1567312880, COSV57043246; called by muse, mutect2, varscan2
- ECM1 | c.1045T>C p.C349R | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777173556, COSV60871768; called by muse, mutect2, varscan2
- EEA1 | c.300+2T>C p.X100_splice | Splice Site (SNP) | VAF 133/397 reads (34%) | catalogued as COSV59284236; called by muse, mutect2, varscan2
- EEF1A2 | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 101/338 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV53205531; called by muse, mutect2, varscan2
- EEF1AKMT4 | c.538dup p.H180Pfs*68 | Frame Shift Ins (INS) | VAF 119/465 reads (26%) | catalogued as rs751055758; called by mutect2, pindel, varscan2
- EFCAB5 | c.450dup p.L151Tfs*3 | Frame Shift Ins (INS) | VAF 12/48 reads (25%) | catalogued as rs760813779; called by mutect2, varscan2
- EFCAB5 | c.3746C>T p.T1249M | Missense Mutation (SNP) | VAF 80/270 reads (30%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.921); catalogued as rs781519608, COSV57927106; called by muse, mutect2, varscan2
- EGFLAM | c.2405G>T p.R802M | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); catalogued as COSV59297661; called by muse, mutect2, varscan2
- EGR1 | c.1000dup p.H334Pfs*13 | Frame Shift Ins (INS) | VAF 118/400 reads (30%) | catalogued as rs746692720; called by mutect2, varscan2
- ELOB | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs776112584, COSV51942106; called by muse, mutect2, varscan2
- ELOF1 | c.227A>G p.D76G | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52947415, COSV52947587; called by muse, mutect2, varscan2
- EMILIN2 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 72/222 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs201232565, COSV54422496; called by muse, mutect2, varscan2
- EML1 | c.2176G>C p.G726R | Missense Mutation (SNP) | VAF 120/416 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV51743194; called by muse, mutect2, varscan2
- EMP3 | c.398del p.G133Afs*? | Frame Shift Del (DEL) | VAF 45/222 reads (20%) | catalogued as rs1275937883; called by mutect2, pindel, varscan2
- EMSY | c.244A>G p.N82D | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); catalogued as COSV58258875; called by muse, mutect2, varscan2
- EOGT | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 167/538 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs1359276220, COSV55150256; called by muse, mutect2, varscan2
- EPHA5 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.01); catalogued as COSV99896950; called by muse, mutect2, varscan2
- EPN1 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs754608786, COSV50036384, COSV99321587; called by muse, mutect2, varscan2
- EPN1 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV50036400; called by mutect2, varscan2
- EPRS1 | c.2312A>T p.K771I | Missense Mutation (SNP) | VAF 110/349 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65098220; called by muse, mutect2, varscan2
- EPRS1 | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 79/294 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as COSV65098224; called by muse, mutect2, varscan2
- ERAP2 | c.1413G>T p.E471D | Missense Mutation (SNP) | VAF 118/354 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as COSV65939300; called by muse, varscan2
- ERCC3 | c.1469A>G p.E490G | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV53426494; called by muse, mutect2, varscan2
- ERCC6 | c.3042G>T p.Q1014H | Missense Mutation (SNP) | VAF 175/563 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.199); catalogued as COSV63388967; called by muse, mutect2, varscan2
- ERICH3 | c.2773G>A p.A925T | Missense Mutation (SNP) | VAF 178/520 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV58603424; called by muse, mutect2, varscan2
- ERN1 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as COSV70501329; called by muse, mutect2, varscan2
- ESPL1 | c.3583G>A p.A1195T | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200640004, COSV57758575; called by muse, mutect2, varscan2
- ESR1 | c.240del p.Y80* | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | catalogued as COSV52786512; called by mutect2, pindel, varscan2
- ETF1 | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 134/394 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs1286502948, COSV62127197; called by muse, mutect2, varscan2
- ETFB | c.506del p.G169Afs*7 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as COSV100164273, COSV58536345; called by mutect2, varscan2
- EVC2 | c.2951C>A p.A984D | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.416); catalogued as COSV60390836; called by muse, mutect2, varscan2
- EXOC1 | c.668A>C p.E223A | Missense Mutation (SNP) | VAF 154/449 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.019); catalogued as COSV62119754; called by muse, mutect2, varscan2
- EXOC1 | c.2470G>T p.G824C | Missense Mutation (SNP) | VAF 97/279 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62119766, COSV62121624; called by muse, mutect2, varscan2
- EXOSC10 | c.1904C>A p.A635E | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100442233; called by muse, mutect2, varscan2
- EYA3 | c.1505T>C p.F502S | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65816203; called by muse, mutect2, varscan2
- EYA3 | c.296T>C p.L99P | Missense Mutation (SNP) | VAF 184/518 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65816211; called by muse, varscan2
- EZR | c.1439C>A p.P480Q | Missense Mutation (SNP) | VAF 81/267 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.044); catalogued as COSV99791640; called by muse, mutect2, varscan2
- FAAP100 | c.2444A>G p.Q815R | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as COSV100585249; called by muse, mutect2, varscan2
- FAHD2A | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 86/302 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs766633125, COSV51977897; called by muse, mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | catalogued as rs751966944; called by mutect2, varscan2
- FAM111B | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV59111463, COSV59111530; called by muse, mutect2, varscan2
- FAM120B | c.1909T>C p.C637R | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.101); catalogued as rs1438590515, COSV53002727; called by muse, mutect2, varscan2
- FAM135B | c.3887T>C p.L1296P | Missense Mutation (SNP) | VAF 73/258 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52716352; called by muse, mutect2, varscan2
- FAM13A | c.3046A>T p.R1016* | Nonsense Mutation (SNP) | VAF 64/214 reads (30%) | catalogued as COSV52000205; called by muse, mutect2, varscan2
- FAM187B | c.709G>T p.G237* | Nonsense Mutation (SNP) | VAF 38/123 reads (31%) | catalogued as COSV61201127; called by muse, mutect2, varscan2
- FAM193A | c.2497del p.M833Wfs*23 | Frame Shift Del (DEL) | VAF 95/263 reads (36%) | catalogued as rs768952789; called by mutect2, varscan2
- FAM20B | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 82/291 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs772062570, COSV55379766; called by muse, mutect2, varscan2
- FAM53C | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs777338677, COSV53511210; called by muse, mutect2, varscan2
- FAM83D | c.1543del p.H515Tfs*6 | Frame Shift Del (DEL) | VAF 35/131 reads (27%) | catalogued as rs754952124; called by mutect2, pindel, varscan2
- FAM83H | c.1774G>A p.G592S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1230011427, COSV66353684; called by muse, mutect2, varscan2
- FANCI | c.2115A>G p.I705M | Missense Mutation (SNP) | VAF 198/521 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV55525365; called by muse, mutect2, varscan2
- FAP | c.1813A>G p.R605G | Missense Mutation (SNP) | VAF 107/343 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV51860712; called by muse, mutect2, varscan2
- FAR1 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 97/322 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.211); catalogued as rs753671320, COSV61384504; called by muse, mutect2, varscan2
- FASTKD2 | c.483G>T p.E161D | Missense Mutation (SNP) | VAF 127/418 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV52697865; called by muse, mutect2, varscan2
- FAT4 | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.189); catalogued as COSV67883720; called by muse, mutect2, varscan2
- FAT4 | c.10529C>A p.P3510H | Missense Mutation (SNP) | VAF 126/366 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58678612; called by muse, mutect2, varscan2
- FBF1 | c.1525A>G p.T509A (on ENST00000586717; = p.T523A on NM_001319193.1) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59864277; called by muse, mutect2, varscan2
- FBN1 | c.6946T>C p.C2316R | Missense Mutation (SNP) | VAF 60/206 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM098720; called by muse, varscan2
- FBN2 | c.5111G>T p.G1704V | Missense Mutation (SNP) | VAF 109/297 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52505120; called by muse, mutect2, varscan2
- FBN3 | c.5293G>A p.D1765N | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as rs759106137, COSV54452904; called by muse, mutect2, varscan2
- FBN3 | c.2542C>T p.R848C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.765); catalogued as rs571909633, COSV54457414; called by mutect2, varscan2
- FBXL19 | c.614del p.P205Rfs*26 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | catalogued as rs745385709; called by mutect2, varscan2
- FBXO15 | c.1516T>C p.F506L | Missense Mutation (SNP) | VAF 117/450 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as COSV99503119; called by muse, mutect2, varscan2
- FBXO24 | c.805A>T p.I269F (on ENST00000241071 / NM_033506.3; = p.I307F on NM_012172.5) | Missense Mutation (SNP) | VAF 131/420 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV99575059; called by muse, mutect2, varscan2
- FBXW2 | c.753A>C p.K251N | Missense Mutation (SNP) | VAF 125/340 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1221663608, COSV61596717; called by muse, mutect2, varscan2
- FCGRT | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.63); catalogued as COSV55529194; called by muse, mutect2, varscan2
- FCRL3 | c.1436C>T p.T479I | Missense Mutation (SNP) | VAF 91/258 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); catalogued as COSV63840587; called by muse, mutect2, varscan2
- FERMT3 | c.271C>A p.L91I | Missense Mutation (SNP) | VAF 181/501 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1003429411, COSV54178341; called by muse, mutect2, varscan2
- FFAR4 | c.911T>C p.L304P | Missense Mutation (SNP) | VAF 193/547 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65159881; called by muse, mutect2, varscan2
- FGF13 | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 230/708 reads (32%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.469); catalogued as COSV59544278; called by muse, mutect2, varscan2
- FGFR4 | c.2167C>T p.R723C | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs201490532, COSV52802140; called by muse, mutect2, varscan2
- FIBCD1 | c.1259A>G p.N420S | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53392988; called by muse, mutect2, varscan2
- FITM2 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as rs370245406; called by muse, mutect2, varscan2
- FLI1 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55643674; called by muse, mutect2, varscan2
- FLNA | c.3353G>T p.G1118V | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61040689; called by muse, mutect2, varscan2
- FLNC | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 93/229 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778751919, COSV57953517; called by muse, mutect2, varscan2
- FMN2 | c.2246C>T p.T749M | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs371967368, COSV60425593; called by muse, mutect2, varscan2
- FOSB | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as rs764116136; called by muse, mutect2, varscan2
- FPGT | c.1657A>C p.T553P | Missense Mutation (SNP) | VAF 93/309 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.309); catalogued as COSV63837479; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1161del p.L388Yfs*25 | Frame Shift Del (DEL) | VAF 128/498 reads (26%) | catalogued as rs1291679708, COSV100437911; called by mutect2, pindel, varscan2
- FRAS1 | c.2098A>G p.R700G | Missense Mutation (SNP) | VAF 146/624 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV53601550; called by muse, mutect2, varscan2
- FRMD6 | c.904T>C p.Y302H (on ENST00000344768 / NM_001267046.2; = p.Y294H on NM_152330.4) | Missense Mutation (SNP) | VAF 75/232 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61087285; called by muse, mutect2, varscan2
- FRY | c.1840C>T p.R614* | Nonsense Mutation (SNP) | VAF 158/496 reads (32%) | catalogued as rs776773297, COSV66567927; called by muse, mutect2, varscan2
- FSCN2 | c.593G>A p.G198D | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100603243; called by muse, mutect2
- FSIP2 | c.18980A>C p.D6327A | Missense Mutation (SNP) | VAF 71/186 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58082673; called by muse, mutect2, varscan2
- FSTL4 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs200915266, COSV54767571; called by muse, mutect2, varscan2
- FURIN | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51575836; called by muse, mutect2, varscan2
- FUT1 | c.461A>G p.Y154C | Missense Mutation (SNP) | VAF 149/490 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM973075, COSV59567934; called by muse, mutect2, varscan2
- FZD1 | c.341G>A p.G114D | Missense Mutation (SNP) | VAF 107/278 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.609); catalogued as rs751566731, COSV55309825; called by muse, mutect2, varscan2
- FZD1 | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 255/641 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55309837; called by muse, mutect2, varscan2
- GAB3 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 118/403 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1557257611, COSV65819365; called by muse, varscan2
- GALC | c.1888T>C p.Y630H | Missense Mutation (SNP) | VAF 262/861 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.031); catalogued as CD972224, COSV54324432; called by mutect2, varscan2
- GALNT10 | c.1319C>T p.T440M | Missense Mutation (SNP) | VAF 125/419 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.129); catalogued as rs147745456; called by muse, mutect2, varscan2
- GALNT12 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 207/634 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs776700061, COSV66662346; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GALNTL6 | c.879del p.I294Sfs*41 | Frame Shift Del (DEL) | VAF 56/188 reads (30%) | catalogued as COSV101560007; called by mutect2, pindel, varscan2
- GALR1 | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 37/136 reads (27%) | catalogued as COSV55316569; called by muse, mutect2, varscan2
- GAN | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 145/451 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.365); catalogued as rs574374537, COSV73720739, COSV73720828; called by muse, mutect2, varscan2
- GATA3 | c.944C>T p.T315M | Missense Mutation (SNP) | VAF 82/286 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CD003632, COSV60517092; called by muse, varscan2
- GATAD2B | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 180/548 reads (33%) | catalogued as COSV64083769; called by muse, mutect2, varscan2
- GBA2 | c.1159G>T p.G387C | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV62305537; called by muse, mutect2, varscan2
- GBA3 | c.1042G>A p.V348M | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.369); catalogued as rs915467565, COSV101545482; called by muse, mutect2, varscan2
- GCM1 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 88/225 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs764579596, COSV52521405; called by muse, mutect2, varscan2
- GDA | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 38/132 reads (29%) | catalogued as COSV52993755; called by muse, mutect2, varscan2
- GDAP1 | c.886G>A p.V296I | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.052); catalogued as COSV55185302; called by muse, mutect2, varscan2
- GDF5 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs763209567, COSV65500436; called by muse, mutect2, varscan2
- GDPD5 | c.790A>G p.T264A | Missense Mutation (SNP) | VAF 123/364 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV61127014; called by muse, mutect2, varscan2
- GET4 | c.542A>G p.E181G | Missense Mutation (SNP) | VAF 113/364 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56253638; called by muse, mutect2, varscan2
- GFRA1 | c.832C>A p.L278I | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.807); catalogued as COSV62604350; called by muse, mutect2, varscan2
- GGA2 | c.910A>G p.T304A | Missense Mutation (SNP) | VAF 71/225 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV59168023; called by muse, mutect2, varscan2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs763147690; called by mutect2, varscan2
- GIGYF2 | c.1455A>T p.E485D | Missense Mutation (SNP) | VAF 189/548 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs547560862, COSV65248087; called by muse, mutect2, varscan2
- GJA10 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 180/591 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV65354722; called by muse, mutect2, varscan2
- GLB1 | c.10T>C p.F4L | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV56562750; called by mutect2, varscan2
- GLB1L3 | c.1627A>G p.T543A | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV68392548; called by muse, mutect2, varscan2
- GLRA2 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 99/307 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54338753; called by muse, mutect2, varscan2
- GMPPA | c.1195A>G p.I399V | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV58006524; called by muse, mutect2, varscan2
- GNE | c.1862A>G p.Y621C (on ENST00000396594 / NM_001128227.3; = p.Y590C on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/244 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as rs1363913351, COSV64951577; called by muse, mutect2, varscan2
- GNG12 | c.202dup p.T68Nfs*9 | Frame Shift Ins (INS) | VAF 70/265 reads (26%) | catalogued as rs1022402829; called by mutect2, varscan2
- GOLGA3 | c.3824A>C p.Q1275P | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV99202324; called by muse, mutect2, varscan2
- GOLGA4 | c.14T>C p.L5P | Missense Mutation (SNP) | VAF 110/290 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57887342; called by muse, mutect2, varscan2
- GPA33 | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 29/357 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63302462; called by muse, mutect2
- GPR4 | c.428C>A p.A143D | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); catalogued as rs1303575895, COSV59916559; called by muse, mutect2, varscan2
- GPSM1 | c.770A>G p.N257S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100696560; called by muse, mutect2, varscan2
- GREB1 | c.1664G>A p.S555N | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV52184163, COSV52185751; called by muse, mutect2, varscan2
- GRIK1 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 86/185 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs539327767, COSV58710129; called by muse, mutect2, varscan2
- GRK2 | c.662G>A p.C221Y | Missense Mutation (SNP) | VAF 81/208 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV57951259; called by muse, mutect2, varscan2
- GRM6 | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.066); catalogued as rs377276357; called by muse, mutect2, varscan2
- GRM7 | c.2099C>A p.T700K | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.991); catalogued as rs752445160, COSV63137545, COSV63161207; called by muse, mutect2, varscan2
- GRM8 | c.1707C>A p.C569* | Nonsense Mutation (SNP) | VAF 60/202 reads (30%) | catalogued as COSV58816588; called by muse, mutect2, varscan2
- GTF3C1 | c.2027G>A p.R676Q | Missense Mutation (SNP) | VAF 57/196 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs1345925592, COSV62239081; called by muse, mutect2, varscan2
- GUF1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.38); catalogued as COSV55782091; called by muse, mutect2, varscan2
- GZF1 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57635636; called by muse, mutect2, varscan2
- H1-5 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1207966785, COSV58899627; called by muse, mutect2, varscan2
- H2BC13 | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 181/520 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV62440465; called by muse, mutect2, varscan2
- H2BC18 | c.271A>G p.T91A | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.282); catalogued as COSV100516047; called by mutect2, varscan2
- H2BC4 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 137/468 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.148); catalogued as rs942484360, COSV58415514; called by muse, mutect2, varscan2
- HBS1L | c.1843C>T p.R615* | Nonsense Mutation (SNP) | VAF 78/247 reads (32%) | catalogued as CM1311869, COSV63200929; called by muse, mutect2, varscan2
- HCFC1 | c.2822C>T p.A941V | Missense Mutation (SNP) | VAF 73/225 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.956); catalogued as COSV60071094; called by muse, mutect2, varscan2
- HCN4 | c.766C>T p.H256Y | Missense Mutation (SNP) | VAF 75/246 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56082543; called by muse, mutect2, varscan2
- HDAC4 | c.2703dup p.M902Hfs*5 | Frame Shift Ins (INS) | VAF 9/50 reads (18%) | catalogued as rs747537946; called by mutect2, varscan2
- HEATR5A | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 81/252 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV66339523; called by muse, mutect2, varscan2
- HECTD4 | c.13100del p.P4367Qfs*21 | Frame Shift Del (DEL) | VAF 54/191 reads (28%) | catalogued as rs746492036; called by mutect2, pindel, varscan2
- HERC1 | c.3506C>T p.T1169I | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as COSV71247051; called by muse, mutect2, varscan2
- HES4 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766490059, COSV59242081; called by muse, mutect2, varscan2
- HGS | c.2248del p.Q750Sfs*50 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | catalogued as rs748765403; called by mutect2, pindel, varscan2
- HIC1 | c.1046G>A p.R349H (on ENST00000322941 / NM_001098202.1; = p.R330H on NM_006497.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.339); catalogued as rs1438425349; called by muse, mutect2
- HIC2 | c.686del p.G229Afs*45 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs1218980629; called by mutect2, pindel, varscan2
- HID1 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 84/244 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs746182882, COSV100585947; called by muse, varscan2
- HIF1A | c.112del p.Y38Mfs*13 | Frame Shift Del (DEL) | VAF 28/247 reads (11%) | catalogued as rs760088435; called by mutect2, pindel, varscan2
- HK1 | c.2326C>A p.L776M | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1054203; called by muse, mutect2, varscan2
- HK3 | c.2138T>C p.M713T | Missense Mutation (SNP) | VAF 79/266 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.022); catalogued as COSV52838506; called by muse, mutect2, varscan2
- HLA-A | c.155T>C p.V52A | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65139169; called by muse, varscan2
- HLA-B | c.240del p.P81Rfs*70 | Frame Shift Del (DEL) | VAF 73/197 reads (37%) | catalogued as COSV69521421; called by mutect2, varscan2
- HLA-C | c.425A>C p.Y142S | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV66111908; called by muse, mutect2, varscan2
- HLA-DRA | c.607T>C p.W203R | Missense Mutation (SNP) | VAF 85/258 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV66622653; called by muse, mutect2, varscan2
- HMG20B | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs762900877, COSV99502985; called by muse, mutect2, varscan2
- HMGB4 | c.448A>G p.R150G | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV53898856; called by muse, mutect2, varscan2
- HMMR | c.709A>G p.I237V | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as rs1187765108, COSV62374244; called by muse, mutect2, varscan2
- HNF1A | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs760640415, COSV57461054; called by muse, mutect2, varscan2
- HOXB2 | c.272del p.P91Rfs*8 | Frame Shift Del (DEL) | VAF 24/97 reads (25%) | catalogued as rs761024113; called by mutect2, pindel, varscan2
- HOXC9 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 86/301 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777643587, COSV57716328; called by muse, mutect2, varscan2
- HPN | c.908-1G>T p.X303_splice | Splice Site (SNP) | VAF 25/62 reads (40%) | catalogued as COSV52883050; called by muse, mutect2, varscan2
- HRH2 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51573559; called by muse, mutect2, varscan2
- HS6ST2 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 24/84 reads (29%) | catalogued as rs1456848709, COSV63711933; called by muse, mutect2, varscan2
- HSPA2 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV55969203; called by muse, mutect2, varscan2
- HSPA4L | c.2167-2A>G p.X723_splice | Splice Site (SNP) | VAF 57/152 reads (38%) | catalogued as COSV99612664; called by muse, mutect2, varscan2
- HSPB8 | c.266dup p.P90Tfs*37 | Frame Shift Ins (INS) | VAF 10/44 reads (23%) | catalogued as rs773017653; called by mutect2, varscan2
- HUWE1 | c.11987T>C p.V3996A | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV53340727; called by muse, mutect2, varscan2
- HVCN1 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 97/307 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs781358524, COSV54371702; called by muse, mutect2, varscan2
- HYDIN | c.13528G>T p.G4510W | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101124944; called by mutect2, varscan2
- HYDIN | c.9224G>A p.R3075H | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs569134886, COSV59253771; called by muse, mutect2, varscan2
- HYDIN | c.4361T>C p.V1454A | Missense Mutation (SNP) | VAF 123/468 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV101141474; called by muse, mutect2, varscan2
- IARS2 | c.1513T>G p.S505A | Missense Mutation (SNP) | VAF 159/483 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV56958808; called by muse, mutect2, varscan2
- IER3IP1 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 51/200 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV56505930; called by muse, mutect2, varscan2
- IFRD2 | c.386A>G p.D129G | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV57113195; called by muse, mutect2, varscan2
- IFT140 | c.101A>G p.Y34C | Missense Mutation (SNP) | VAF 149/482 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.428); catalogued as COSV68487314; called by muse, mutect2, varscan2
- IFT80 | c.893T>C p.V298A | Missense Mutation (SNP) | VAF 164/486 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV58446556; called by muse, mutect2, varscan2
- IGFN1 | c.3406del p.R1136Gfs*8 (on ENST00000295591 / NM_001367841.1; = p.R3593Gfs*8 on NM_001164586.2) | Frame Shift Del (DEL) | VAF 15/67 reads (22%) | catalogued as rs774748743; called by mutect2, pindel, varscan2
- IGHMBP2 | c.1129T>C p.C377R | Missense Mutation (SNP) | VAF 87/254 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1409138201, COSV54821549; called by muse, mutect2, varscan2
- IGSF1 | c.2588C>A p.P863H | Missense Mutation (SNP) | VAF 236/773 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63836854; called by muse, mutect2, varscan2
- IGSF21 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 71/218 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1378720517, COSV52129911, COSV52131696; called by muse, mutect2, varscan2
- IGSF9 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | catalogued as rs950811935, COSV63639516; called by muse, mutect2, varscan2
- IL13RA2 | c.1141T>C p.*381Rext*23 | Nonstop Mutation (SNP) | VAF 53/126 reads (42%) | catalogued as rs1556506999, COSV54564664; called by muse, mutect2, varscan2
- IL27RA | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 57/152 reads (38%) | catalogued as rs746755376, COSV54599991; called by muse, mutect2, varscan2
- ILDR2 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs748481777, COSV54831741; called by muse, mutect2, varscan2
- IMMP2L | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 77/212 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV59227710; called by muse, mutect2, varscan2
- ING5 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 132/447 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV57978372; called by muse, mutect2, varscan2
- INPP1 | c.1160T>C p.L387P | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.054); catalogued as COSV59415526; called by muse, mutect2
- INTS1 | c.2932C>T p.R978C | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375709617; called by muse, mutect2, varscan2
- INTS1 | c.2063C>T p.A688V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.047); catalogued as rs367966750; called by muse, varscan2
- INTS6L | c.2221G>T p.G741* | Nonsense Mutation (SNP) | VAF 82/277 reads (30%) | catalogued as COSV66084068; called by muse, mutect2, varscan2
- IQGAP1 | c.3631C>A p.L1211M | Missense Mutation (SNP) | VAF 77/211 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs535117997, COSV51583414; called by muse, mutect2, varscan2
- IQGAP3 | c.1298G>A p.G433D | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV63250510; called by muse, mutect2, varscan2
- IQSEC2 | c.1849C>T p.R617C (on ENST00000642864 / NM_001111125.3; = p.R412C on NM_015075.2) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); catalogued as rs1556863213, COSV64724638; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IQSEC3 | c.2423A>T p.D808V (on ENST00000538872 / NM_001170738.2; = p.D505V on NM_015232.1) | Missense Mutation (SNP) | VAF 123/428 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV58283126; called by muse, mutect2, varscan2
- IRAG1 | c.671G>A p.G224D | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV70210523; called by muse, mutect2, varscan2
- IRF3 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 120/352 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.647); catalogued as COSV55862821; called by muse, mutect2, varscan2
- IRS4 | c.1754G>A p.G585D | Missense Mutation (SNP) | VAF 275/912 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.915); catalogued as COSV64533201; called by muse, mutect2, varscan2
- IRX4 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs1278591541, COSV51471877; called by muse, varscan2
- IRX6 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as rs371123518; called by muse, mutect2, varscan2
- ISOC2 | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV50034901; called by muse, mutect2, varscan2
- ITGA1 | c.155A>G p.Q52R | Missense Mutation (SNP) | VAF 144/448 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV99250823; called by muse, mutect2, varscan2
- ITGA1 | c.2854T>C p.F952L | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.23); catalogued as COSV50879119; called by muse, mutect2, varscan2
- ITGA2 | c.3265T>C p.F1089L | Missense Mutation (SNP) | VAF 83/295 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as COSV56858289; called by muse, mutect2, varscan2
- ITGAD | c.1246dup p.V416Gfs*69 | Frame Shift Ins (INS) | VAF 31/134 reads (23%) | catalogued as rs749344035; called by mutect2, pindel, varscan2
- ITGB2 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs374031101; called by muse, mutect2, varscan2
- ITPR1 | c.7027C>T p.R2343* (on ENST00000354582; = p.R2288* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 83/289 reads (29%) | catalogued as rs765004428, COSV56976089; called by muse, mutect2, varscan2
- ITPR3 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777019225, COSV65407660; called by muse, mutect2, varscan2
- ITSN1 | c.4676+2T>C p.X1559_splice | Splice Site (SNP) | VAF 52/135 reads (39%) | catalogued as COSV101181378; called by muse, mutect2, varscan2
- JAKMIP1 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.299); catalogued as COSV99288898; called by muse, mutect2, varscan2
- JPH4 | c.1582G>A p.G528S | Missense Mutation (SNP) | VAF 216/676 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs370087602; called by muse, varscan2
- KANSL1 | c.2788C>T p.R930W (on ENST00000574590 / NM_001193465.2; = p.R931W on NM_015443.4) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377108187; ClinVar: likely benign; called by muse, mutect2, varscan2
- KAT6B | c.6130G>A p.G2044S | Missense Mutation (SNP) | VAF 81/280 reads (29%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); catalogued as rs374969061, COSV99768122; called by muse, mutect2, varscan2
- KATNBL1 | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 100/326 reads (31%) | catalogued as COSV56622657; called by muse, mutect2, varscan2
- KATNIP | c.3259C>T p.R1087* | Nonsense Mutation (SNP) | VAF 70/212 reads (33%) | catalogued as rs771883563, COSV55177228; called by muse, mutect2, varscan2
- KCNA2 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60369560; called by muse, mutect2, varscan2
- KCNB2 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 78/284 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs547685470, COSV73048891; called by muse, mutect2, varscan2
- KCND2 | c.490A>G p.T164A | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV58575182; called by muse, mutect2, varscan2
- KCNG2 | c.203A>G p.E68G | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100301665; called by muse, mutect2, varscan2
- KCNG4 | c.1520T>G p.L507R | Missense Mutation (SNP) | VAF 186/583 reads (32%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV57583310; called by muse, mutect2, varscan2
- KCNH3 | c.484G>T p.G162C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV57790194; called by muse, mutect2, varscan2
- KCNH3 | c.2123del p.G708Efs*11 | Frame Shift Del (DEL) | VAF 38/134 reads (28%) | catalogued as rs1229306184; called by mutect2, pindel, varscan2
- KCNJ8 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.173); catalogued as COSV53717835; called by muse, varscan2
- KCNK10 | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs764537069, COSV56642228, COSV56651207; called by muse, mutect2, varscan2
- KCNQ1 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.781); catalogued as rs765665086, CM136618, COSV50103907; called by muse, mutect2, varscan2
- KCNS2 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54637980; called by muse, mutect2, varscan2
- KCNU1 | c.3050T>C p.V1017A | Missense Mutation (SNP) | VAF 170/552 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV101299449, COSV67754643; called by muse, mutect2, varscan2
- KDELR1 | c.28C>A p.L10I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV54377977; called by muse, mutect2, varscan2
- KDM2B | c.3016del p.R1006Gfs*37 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | catalogued as rs1555288650, COSV65639291; called by mutect2, pindel, varscan2
- KDM2B | c.2722G>A p.D908N | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs895569064, COSV65639369; called by muse, mutect2, varscan2
- KDM2B | c.271+2T>C p.X91_splice | Splice Site (SNP) | VAF 19/51 reads (37%) | catalogued as COSV100997263; called by muse, mutect2
- KDM4B | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as rs1001771201, COSV50214318; called by muse, mutect2
- KHNYN | c.338C>A p.P113H | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV52159673; called by muse, mutect2, varscan2
- KIAA1549 | c.4427dup p.E1477Gfs*3 | Frame Shift Ins (INS) | VAF 20/98 reads (20%) | catalogued as rs752867430; called by mutect2, pindel, varscan2
- KIAA1549L | c.3351G>T p.M1117I (on ENST00000321505; = p.M1414I on NM_012194.3) | Missense Mutation (SNP) | VAF 67/210 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.247); catalogued as COSV55771677; called by muse, mutect2, varscan2
- KIAA1958 | c.860T>C p.V287A | Missense Mutation (SNP) | VAF 60/1242 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs780092148, COSV61728592; called by muse, mutect2
- KIF1C | c.172T>C p.S58P | Missense Mutation (SNP) | VAF 127/438 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57903891; called by muse, mutect2, varscan2
- KIF1C | c.2479G>T p.G827W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV57902855; called by muse, mutect2, varscan2
- KIF20A | c.2667G>C p.K889N | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV67509629; called by muse, mutect2, varscan2
- KIF4B | c.2507A>G p.D836G | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV70528673; called by muse, mutect2, varscan2
- KIFC2 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 92/256 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.027); catalogued as rs756190794, COSV56760600; called by muse, mutect2, varscan2
- KIFC3 | c.1556G>A p.G519D | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101109107; called by muse, varscan2
- KIR2DL3 | c.1007T>G p.L336R | Missense Mutation (SNP) | VAF 373/1175 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60896756; called by muse, mutect2, varscan2
- KIRREL2 | c.1953del p.C652Afs*79 | Frame Shift Del (DEL) | VAF 126/362 reads (35%) | catalogued as rs761116739, COSV52880030; called by mutect2, pindel, varscan2
- KLHL13 | c.1499C>A p.T500N | Missense Mutation (SNP) | VAF 44/724 reads (6%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.698); catalogued as COSV53246383; called by muse, mutect2
- KLHL25 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as rs542141942, COSV61994719; called by muse, mutect2, varscan2
- KLHL34 | c.861del p.R288Afs*7 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | catalogued as rs762518653; called by mutect2, pindel, varscan2
- KLHL5 | c.1292A>G p.D431G | Missense Mutation (SNP) | VAF 96/268 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV54673107; called by muse, mutect2, varscan2
- KLHL5 | c.2145dup p.Y716Vfs*2 | Frame Shift Ins (INS) | VAF 51/192 reads (27%) | catalogued as rs1213171273; called by mutect2, pindel, varscan2
- KLKB1 | c.418del p.R140Gfs*29 | Frame Shift Del (DEL) | VAF 56/218 reads (26%) | catalogued as rs755680952; called by mutect2, pindel, varscan2
- KMT2D | c.4840C>T p.R1614W | Missense Mutation (SNP) | VAF 69/192 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375118713; called by muse, mutect2, varscan2
- KMT5C | c.106G>A p.V36I | Missense Mutation (SNP) | VAF 68/197 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.054); catalogued as rs774927761, COSV55318841, COSV55320455; called by muse, mutect2, varscan2
- KNOP1 | c.467dup p.A158Gfs*16 | Frame Shift Ins (INS) | VAF 28/101 reads (28%) | catalogued as COSV54926489; called by mutect2, varscan2
- KRI1 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1420809267, COSV57264183; called by muse, varscan2
- KRT14 | c.200del p.G67Afs*51 | Frame Shift Del (DEL) | VAF 22/43 reads (51%) | catalogued as rs769596857; called by mutect2, pindel, varscan2
- KRT2 | c.1225dup p.E409Gfs*10 | Frame Shift Ins (INS) | VAF 38/118 reads (32%) | catalogued as rs1260366085; called by mutect2, pindel, varscan2
- KRT26 | c.961A>G p.M321V | Missense Mutation (SNP) | VAF 126/396 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1433891764, COSV59413627; called by muse, mutect2
- KRT71 | c.1387A>G p.S463G | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs937658685, COSV99922004; called by muse, mutect2, varscan2
- KRTAP5-10 | c.338dup p.C114Lfs*33 | Frame Shift Ins (INS) | VAF 60/214 reads (28%) | catalogued as rs1168942906; called by mutect2, varscan2
- KSR1 | c.872del p.P291Hfs*36 (on ENST00000644974 / NM_001367810.1; = p.P154Hfs*36 on NM_014238.2) | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | catalogued as rs750491454; called by mutect2, varscan2
- L3MBTL1 | c.1832G>T p.R611I (on ENST00000418998 / NM_001377303.1; = p.R521I on NM_015478.7) | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.857); catalogued as COSV64228211; called by muse, mutect2, varscan2
- LAMA1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 86/270 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.019); catalogued as rs367866675; called by muse, mutect2, varscan2
- LAMA3 | c.3185A>G p.N1062S | Missense Mutation (SNP) | VAF 82/248 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.12); catalogued as rs369555108; called by muse, varscan2
- LAMA5 | c.1769G>A p.S590N | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.979); catalogued as COSV53357033; called by muse, mutect2, varscan2
- LANCL3 | c.192del p.L65Ffs*129 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs782221297; called by mutect2, varscan2
- LARS1 | c.774T>C p.G258= (on ENST00000394434 / NM_020117.11; = p.G231= on NM_016460.3) | Splice Region (SNP) | VAF 56/180 reads (31%) | catalogued as COSV50973792; called by muse, mutect2, varscan2
- LCOR | c.3334G>A p.A1112T | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.977); catalogued as rs765812384, COSV53714707; called by muse, mutect2, varscan2
- LDLR | c.2547G>A p.S849= | Splice Region (SNP) | VAF 60/185 reads (32%) | catalogued as rs1249903899, COSV52942534; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LGALS8 | c.383A>G p.H128R | Missense Mutation (SNP) | VAF 187/697 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99436301; called by muse, varscan2
- LGR4 | c.2782C>T p.R928* | Nonsense Mutation (SNP) | VAF 127/411 reads (31%) | catalogued as rs1461413137, COSV58725333; called by muse, mutect2, varscan2
- LGR5 | c.2375A>G p.N792S | Missense Mutation (SNP) | VAF 144/492 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.028); catalogued as rs1398317494, COSV57003968; called by muse, varscan2
- LHX2 | c.173G>A p.G58D | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.111); catalogued as COSV65318062; called by muse, mutect2, varscan2
- LIG1 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV54390579; called by muse, varscan2
- LIG3 | c.469dup p.I157Nfs*16 | Frame Shift Ins (INS) | VAF 31/105 reads (30%) | catalogued as rs745989900; called by mutect2, varscan2
- LIPH | c.932C>A p.P311H | Missense Mutation (SNP) | VAF 31/732 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.208); catalogued as CD160179, COSV99956379; called by muse, mutect2
- LIPT1 | c.813G>A p.W271* | Nonsense Mutation (SNP) | VAF 51/145 reads (35%) | catalogued as COSV60739512; called by muse, mutect2, varscan2
- LLGL2 | c.2510C>T p.A837V | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1282229640, COSV99389149; called by muse, mutect2, varscan2
- LMAN2L | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs1289758319, COSV53841224; called by muse, mutect2, varscan2
- LMNTD1 | c.770A>G p.Q257R | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV51445809; called by muse, mutect2, varscan2
- LMO7 | c.1882C>T p.R628C (on ENST00000357063; = p.R358C on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/198 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs190179934, COSV58530576; called by muse, mutect2, varscan2
- LMOD1 | c.1336A>G p.T446A | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV100939100; called by muse, varscan2
- LPO | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs771008787, COSV51857909; called by muse, mutect2, varscan2
- LRFN3 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55817313; called by muse, mutect2, varscan2
- LRGUK | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs200351099; called by muse, mutect2, varscan2
- LRIG2 | c.404T>C p.I135T | Missense Mutation (SNP) | VAF 105/295 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV63161560; called by muse, mutect2, varscan2
- LRIT1 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 90/269 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.574); catalogued as COSV64512235; called by muse, mutect2, varscan2
- LRP12 | c.668T>C p.L223S | Missense Mutation (SNP) | VAF 165/454 reads (36%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.998); catalogued as COSV52627452; called by muse, mutect2, varscan2
- LRP1B | c.11895T>C p.C3965= | Splice Region (SNP) | VAF 71/273 reads (26%) | catalogued as COSV101253843; called by muse, mutect2, varscan2
- LRP2 | c.10652G>A p.R3551H | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs545303364, COSV55548085; called by muse, mutect2, varscan2
- LRP3 | c.2296G>A p.A766T | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV53503249, COSV53505126; called by muse, mutect2, varscan2
- LRRC17 | c.989A>G p.N330S | Missense Mutation (SNP) | VAF 161/527 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV50864398; called by muse, mutect2, varscan2
- LRRC25 | c.898T>C p.Y300H | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV53250739; called by muse, mutect2
- LRRC28 | c.797A>C p.E266A | Missense Mutation (SNP) | VAF 105/329 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV57337000; called by muse, mutect2, varscan2
- LRRC8D | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs773687858, COSV61578411; called by muse, mutect2, varscan2
- LRRFIP1 | c.842C>T p.T281I (on ENST00000392000 / NM_001137552.2; = p.T257I on NM_004735.4) | Missense Mutation (SNP) | VAF 93/337 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55250396; called by muse, mutect2
- LTBP4 | c.3977del p.P1326Hfs*103 (on ENST00000308370 / NM_001042544.1; = p.P1289Hfs*103 on NM_003573.2) | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | catalogued as COSV52588056; called by mutect2, pindel
- LUZP1 | c.2782C>T p.R928* | Nonsense Mutation (SNP) | VAF 120/411 reads (29%) | catalogued as COSV56500113; called by muse, mutect2, varscan2
- LUZP4 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 32/696 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs936115318, COSV64218417; called by muse, mutect2
- LY6G6F-LY6G6D | c.899T>C p.L300P | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.502); catalogued as COSV101010808; called by muse, mutect2, varscan2
- LY9 | c.1618A>G p.N540D | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.169); catalogued as COSV99626313; called by muse, mutect2, varscan2
- LYST | c.10373C>T p.P3458L | Missense Mutation (SNP) | VAF 53/236 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs1221940973, COSV67714806; called by muse, mutect2, varscan2
- MACF1 | c.17293A>G p.S5765G (on ENST00000372915; = p.S3807G on NM_012090.5) | Missense Mutation (SNP) | VAF 91/322 reads (28%) | catalogued as COSV57115097; called by muse, mutect2, varscan2
- MAGEL2 | c.3325A>G p.K1109E | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.275); catalogued as COSV58566524; called by muse, mutect2, varscan2
- MAGIX | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 158/552 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as COSV66255857; called by muse, mutect2, varscan2
- MAN1C1 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs867433498, COSV56043914; called by muse, mutect2, varscan2
- MAN1C1 | c.1366G>A p.G456R | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769693980, COSV56043923; called by muse, mutect2, varscan2
- MAP1A | c.2020G>A p.A674T | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs376517161; called by muse, mutect2, varscan2
- MAP1A | c.4154C>T p.T1385I | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs1190233308, COSV55807625; called by muse, mutect2, varscan2
- MAP1S | c.2560del p.R854Gfs*156 | Frame Shift Del (DEL) | VAF 20/78 reads (26%) | catalogued as COSV60722182; called by mutect2, pindel, varscan2
- MAP2K5 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 123/372 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs532904399, COSV51612620; called by muse, mutect2, varscan2
- MAP2K7 | c.1225G>A p.V409I | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.005); catalogued as rs775112625, COSV67607944; called by muse, mutect2, varscan2
- MAP3K1 | c.3931G>T p.G1311* | Nonsense Mutation (SNP) | VAF 62/199 reads (31%) | catalogued as COSV68122853; called by muse, mutect2, varscan2
- MAP3K21 | c.2873A>T p.Q958L | Missense Mutation (SNP) | VAF 63/186 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV64041417; called by muse, varscan2
- MAP3K21 | c.2908C>T p.Q970* | Nonsense Mutation (SNP) | VAF 63/201 reads (31%) | catalogued as rs758435545, COSV64041428; called by muse, varscan2
- MAP4K2 | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV53642034; called by muse, mutect2, varscan2
- MARCHF4 | c.517G>T p.G173W | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56104209, COSV56109582; called by muse, mutect2
- MARK1 | c.1537C>T p.R513* | Nonsense Mutation (SNP) | VAF 231/700 reads (33%) | catalogued as COSV65066674; called by muse, mutect2, varscan2
- MARS2 | c.632A>G p.Y211C | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56571032; called by muse, mutect2, varscan2
- MASTL | c.1994C>A p.S665Y | Missense Mutation (SNP) | VAF 104/357 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs112048111, COSV60910221; called by muse, mutect2, varscan2
- MATN3 | c.509T>C p.M170T | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV68099637; called by muse, mutect2, varscan2
- MBD5 | c.3377T>C p.F1126S | Missense Mutation (SNP) | VAF 81/241 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV68696325; called by muse, mutect2, varscan2
- MCF2 | c.780dup p.L261Ifs*6 | Frame Shift Ins (INS) | VAF 21/115 reads (18%) | catalogued as rs1440858020; called by mutect2, varscan2
- MCM7 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 166/565 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.387); catalogued as rs765971073, COSV57995346; called by muse, mutect2, varscan2
- MDC1 | c.4030C>A p.P1344T | Missense Mutation (SNP) | VAF 156/504 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV64524059; called by muse, mutect2, varscan2
- MDN1 | c.12746A>G p.Q4249R | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.494); catalogued as COSV65519951; called by muse, mutect2, varscan2
- MDN1 | c.3765C>A p.S1255= | Splice Region (SNP) | VAF 26/102 reads (25%) | catalogued as COSV101020882; called by muse, mutect2, varscan2
- MED12 | c.99G>T p.E33D | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV61336158; called by muse, mutect2, varscan2
- MED15 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 84/321 reads (26%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.007); catalogued as COSV53028277; called by muse, mutect2, varscan2
- MEGF8 | c.5007del p.T1670Qfs*60 (on ENST00000251268 / NM_001271938.2; = p.T1603Qfs*60 on NM_001410.3) | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | catalogued as COSV99233906; called by mutect2, pindel, varscan2
- MEPE | c.1526A>G p.D509G | Missense Mutation (SNP) | VAF 313/912 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as COSV63072377; called by muse, mutect2, varscan2
- METTL22 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 133/369 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1385109586, COSV50837558; called by muse, mutect2, varscan2
- MFSD2A | c.1196C>T p.A399V (on ENST00000372809 / NM_001136493.3; = p.A386V on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/226 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139973362; called by muse, mutect2, varscan2
- MICALL1 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 32/112 reads (29%) | catalogued as COSV53239926; called by muse, mutect2, varscan2
- MICOS13 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 118/312 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs546864089, COSV100028484; called by muse, varscan2
- MIER3 | c.1391A>T p.E464V (on ENST00000381199 / NM_001297599.2; = p.E463V on NM_152622.4) | Missense Mutation (SNP) | VAF 129/410 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.796); catalogued as COSV67082714; called by muse, mutect2, varscan2
- MINDY1 | c.1096C>A p.L366M | Missense Mutation (SNP) | VAF 242/716 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56498251; called by muse, mutect2, varscan2
- MLH3 | c.3245T>C p.L1082P | Missense Mutation (SNP) | VAF 153/493 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1163544983; called by muse, mutect2, varscan2
- MLST8 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 28/760 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); catalogued as COSV57027407; called by muse, mutect2
- MMACHC | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 148/530 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV53113422; called by muse, mutect2, varscan2
- MMP9 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 150/493 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs968520149, COSV63433933; called by muse, mutect2, varscan2
- MNDA | c.907G>T p.A303S | Missense Mutation (SNP) | VAF 95/395 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV63740420, COSV63741739; called by muse, mutect2, varscan2
- MOGAT3 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs763725968, COSV56173670; called by muse, mutect2, varscan2
- MON1B | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1271811473, COSV50246034; called by muse, mutect2, varscan2
- MPL | c.500A>G p.Y167C | Missense Mutation (SNP) | VAF 67/219 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV65244537; called by muse, mutect2, varscan2
- MPO | c.2018G>T p.R673L | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51856581, COSV51857911; called by muse, mutect2, varscan2
- MRI1 | c.988del p.H330Tfs*24 (on ENST00000040663 / NM_001031727.4; = p.H283Tfs*24 on NM_032285.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 67/253 reads (26%) | catalogued as rs751646149; called by mutect2, pindel, varscan2
- MROH2B | c.3176T>C p.V1059A | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV101270571; called by muse, mutect2, varscan2
- MRPL19 | c.475+2T>C p.X159_splice | Splice Site (SNP) | VAF 132/428 reads (31%) | catalogued as COSV62566848; called by muse, mutect2, varscan2
- MRTFA | c.1736T>C p.M579T | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.337); catalogued as COSV62932483; called by muse, mutect2, varscan2
- MSL3 | c.1319del p.P440Qfs*22 (on ENST00000312196 / NM_078629.4; = p.P274Qfs*22 on NM_006800.4) | Frame Shift Del (DEL) | VAF 211/880 reads (24%) | catalogued as rs768515139; called by mutect2, pindel, varscan2
- MSX1 | c.893G>A p.S298N | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.749); catalogued as COSV66947506; called by mutect2, varscan2
- MTF2 | c.1188del p.G397Efs*6 | Frame Shift Del (DEL) | VAF 74/198 reads (37%) | catalogued as rs759847587; called by mutect2, varscan2
- MTMR8 | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 94/320 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV66393106; called by muse, mutect2, varscan2
- MTTP | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 101/316 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as rs201464944; called by muse, mutect2, varscan2
- MUC16 | c.35567C>T p.T11856I | Missense Mutation (SNP) | VAF 102/306 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV67456939; called by muse, varscan2
- MUC16 | c.35539del p.T11847Qfs*15 | Frame Shift Del (DEL) | VAF 68/244 reads (28%) | catalogued as rs761846387; called by pindel, varscan2
- MUC17 | c.7511T>C p.V2504A | Missense Mutation (SNP) | VAF 636/1750 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100072032; called by muse, varscan2
- MUC17 | c.10088C>A p.T3363N | Missense Mutation (SNP) | VAF 693/2156 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV60284815; called by muse, mutect2, varscan2
- MUC4 | c.12739A>G p.T4247A | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.028); catalogued as COSV57773033; called by muse, varscan2
- MUC5AC | c.656T>G p.V219G | Missense Mutation (SNP) | VAF 92/264 reads (35%) | SIFT tolerated (0.35); catalogued as COSV100650547; called by muse, mutect2, varscan2
- MUC5B | c.6612dup p.S2205Qfs*54 | Frame Shift Ins (INS) | VAF 20/125 reads (16%) | catalogued as rs1436094024; called by mutect2, pindel, varscan2
- MUC5B | c.9685G>A p.A3229T | Missense Mutation (SNP) | VAF 309/885 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV71591181; called by muse, mutect2, varscan2
- MUS81 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 83/238 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs768086876, COSV57259687; called by muse, mutect2, varscan2
- MUSK | c.506T>C p.V169A | Missense Mutation (SNP) | VAF 266/863 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV51882700; called by muse, mutect2, varscan2
- MVK | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 65/197 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.074); catalogued as rs104895336, CM050697, COSV57330774; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- MVP | c.1747G>A p.V583M | Missense Mutation (SNP) | VAF 82/244 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763449040, COSV62421822; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 13/31 reads (42%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYH11 | c.3500A>G p.E1167G | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55548393; called by muse, mutect2, varscan2
- MYH11 | c.2894C>T p.A965V | Missense Mutation (SNP) | VAF 102/339 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as COSV55548408; called by muse, mutect2, varscan2
- MYH2 | c.3869C>T p.S1290F | Missense Mutation (SNP) | VAF 135/385 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.701); catalogued as COSV55431213; called by muse, mutect2, varscan2
- MYH9 | c.5860G>A p.A1954T | Missense Mutation (SNP) | VAF 109/299 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.013); catalogued as COSV53384222; called by muse, mutect2, varscan2
- MYH9 | c.4592A>T p.E1531V | Missense Mutation (SNP) | VAF 95/278 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53384229; called by muse, mutect2, varscan2
- MYH9 | c.1475A>G p.Y492C | Missense Mutation (SNP) | VAF 114/326 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99338074; called by muse, varscan2
- MYH9 | c.176T>C p.V59A | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53384237; called by muse, mutect2, varscan2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 101/302 reads (33%) | catalogued as rs761471964; called by mutect2, varscan2
- MYO1A | c.1682dup p.T562Dfs*32 | Frame Shift Ins (INS) | VAF 51/192 reads (27%) | catalogued as rs746990682; called by mutect2, pindel, varscan2
- MYO1G | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs371871174; called by muse, mutect2, varscan2
- MYO7A | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101289062; called by muse, mutect2, varscan2
- MYOZ3 | c.107T>G p.L36R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51739644; called by mutect2, varscan2
- NAA35 | c.1307T>G p.I436S | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV64484458; called by muse, mutect2, varscan2
- NAGA | c.1124A>G p.D375G | Missense Mutation (SNP) | VAF 168/542 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1207265226, COSV67169840; called by muse, mutect2, varscan2
- NALCN | c.4262C>T p.A1421V | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.115); catalogued as COSV51927529; called by muse, mutect2, varscan2
- NALCN | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 98/340 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1371989018, COSV51927536; called by muse, mutect2, varscan2
- NAP1L2 | c.225del p.G76Vfs*21 | Frame Shift Del (DEL) | VAF 129/419 reads (31%) | catalogued as CD142825; called by mutect2, pindel, varscan2
- NASP | c.2176A>T p.S726C | Missense Mutation (SNP) | VAF 65/242 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.257); catalogued as COSV59646688; called by muse, mutect2, varscan2
- NASP | c.2177G>C p.S726T | Missense Mutation (SNP) | VAF 64/242 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.189); catalogued as COSV59646694; called by muse, mutect2, varscan2
- NAT8L | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.388); catalogued as COSV59051023; called by muse, mutect2, varscan2
- NBEAL1 | c.7865A>G p.N2622S | Missense Mutation (SNP) | VAF 151/534 reads (28%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs867067449, COSV68915485; called by muse, mutect2, varscan2
- NCAM1 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 76/239 reads (32%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.532); catalogued as rs782167976, COSV57513819; called by muse, mutect2, varscan2
- NCAPD3 | c.2725dup p.Q909Pfs*12 | Frame Shift Ins (INS) | VAF 94/298 reads (32%) | catalogued as rs770284236; called by mutect2, varscan2
- NCKAP5L | c.3217C>A p.L1073M | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); catalogued as COSV100258456; called by muse, mutect2, varscan2
- NCOA1 | c.3987G>T p.Q1329H | Missense Mutation (SNP) | VAF 79/277 reads (29%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.947); catalogued as COSV56042011; called by muse, mutect2, varscan2
- NCOA4 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 98/302 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as rs782570752; called by muse, mutect2, varscan2
- NCOR1 | c.2273A>G p.E758G | Missense Mutation (SNP) | VAF 87/292 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV51969495; called by muse, mutect2, varscan2
1,412 further variants in this file (927 protein-altering or splice-affecting, 437 silent, 48 other) are not listed here.
